Somatic mutation profile of tumor specimen TCGA-CM-6162-01A (aliquot TCGA-CM-6162-01A-11D-1650-10) from TCGA case TCGA-CM-6162, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Ascending colon; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 48.3 years (17,624 days).
Specimen TCGA-CM-6162-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7b8bac0b-6bff-4654-8252-9e469bc6b9f7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CM-6162-10A (Blood Derived Normal), aliquot TCGA-CM-6162-10A-01W-1727-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/843b4e74-0574-4bfc-8d30-49036631d37d

The open-access MAF lists 1,256 somatic variants for this specimen: 917 protein-altering or splice-affecting, 323 silent, 16 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 681, Silent 323, Frame Shift Del 125, Nonsense Mutation 50, Frame Shift Ins 33, Splice Site 11, Splice Region 11, Intron 8, In Frame Del 5, RNA 4, 3'UTR 2, 5'UTR 1.

Variants (750 of 1,256; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARID1A | c.5965C>T p.R1989* | Nonsense Mutation (SNP) | VAF 14/71 reads (20%) | hotspot (GDC flag); catalogued as rs879255270, CM1311944, COSV61370535; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BLM | c.1544del p.N515Mfs*16 | Frame Shift Del (DEL) | VAF 14/65 reads (22%) | catalogued as rs367543043; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- BRCA2 | c.956del p.N319Ifs*5 | Frame Shift Del (DEL) | VAF 42/219 reads (19%) | catalogued as rs80359770; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- CEP290 | c.1666del p.I556Ffs*17 | Frame Shift Del (DEL) | VAF 38/255 reads (15%) | catalogued as rs727503855, CD073590; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- ELN | c.590del p.G197Dfs*126 | Frame Shift Del (DEL) | VAF 14/79 reads (18%) | catalogued as rs863223526; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- EPHB4 | c.2590C>T p.R864W | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769965440, COSV62268518; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- FGF23 | c.527G>A p.R176Q | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as rs104894347, CM002776, COSV52976124; ClinVar: pathogenic; called by muse, mutect2, varscan2
- GABRG2 | c.316G>A p.A106T | Missense Mutation (SNP) | VAF 31/139 reads (22%) | SIFT tolerated (0.66); PolyPhen probably damaging (0.997); catalogued as rs796052505, COSV62721686; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- KMT2C | c.13645C>T p.R4549C | Missense Mutation (SNP) | VAF 37/167 reads (22%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51276981, COSV51294405; called by muse, mutect2, varscan2
- KMT2D | c.16295G>A p.R5432Q | Missense Mutation (SNP) | VAF 36/151 reads (24%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs398123734, CM126446, COSV56409187, COSV99985294; ClinVar: pathogenic / uncertain significance; called by muse, mutect2, varscan2
- MCPH1 | c.321del p.K107Nfs*39 | Frame Shift Del (DEL) | VAF 26/129 reads (20%) | catalogued as rs759663956; ClinVar: pathogenic; called by mutect2, varscan2
- MFRP | c.3del p.H2Tfs*100 (on ENST00000449574; = p.H384Tfs*94 on NM_031433.4) | Frame Shift Del (DEL) | VAF 6/38 reads (16%) | catalogued as rs587776595; ClinVar: pathogenic; called by mutect2, pindel
- MYH7 | c.2011C>T p.R671C | Missense Mutation (SNP) | VAF 55/235 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs727503263, CM031274, COSV62523027; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- NBN | c.1958dup p.L654Afs*5 | Frame Shift Ins (INS) | VAF 41/192 reads (21%) | catalogued as rs780235686; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- NDE1 | c.733del p.L245Sfs*26 (on ENST00000577101; = p.L245Sfs*113 on NM_017668.3) | Frame Shift Del (DEL) | VAF 13/59 reads (22%) | catalogued as rs749768828; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- NMNAT2 | c.695G>A p.R232Q | Missense Mutation (SNP) | VAF 82/313 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs768849266, COSV54271412; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- OTC | c.275G>A p.R92Q | Missense Mutation (SNP) | VAF 129/534 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs66550389, CM062966, CM062967, CM910275, COSV50000649, COSV50002957; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PEX1 | c.1108del p.I370Lfs*17 | Frame Shift Del (DEL) | VAF 54/452 reads (12%) | catalogued as rs61750406; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- PIK3CA | c.263G>A p.R88Q | Missense Mutation (SNP) | VAF 30/157 reads (19%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen probably damaging (0.971); catalogued as rs121913287, CM126688, COSV55874568, COSV55924241; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.323G>A p.R108H | Missense Mutation (SNP) | VAF 23/102 reads (23%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as rs886042002, CM162636, COSV55873442, COSV55926654, COSV55949642; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RNF43 | c.433C>T p.R145* | Nonsense Mutation (SNP) | VAF 15/64 reads (23%) | hotspot (GDC flag); catalogued as rs1458799446, COSV68456834; called by muse, mutect2, varscan2
- SLC12A6 | c.3400C>T p.R1134* (on ENST00000354181 / NM_001365088.1; = p.R1083* on NM_005135.2) | Nonsense Mutation (SNP) | VAF 10/81 reads (12%) | catalogued as rs606231229, CM113902, COSV50784726; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- SLC17A5 | c.1259+1G>A p.X420_splice | Splice Site (SNP) | VAF 25/86 reads (29%) | catalogued as rs146095590, CS031805; ClinVar: likely pathogenic; called by muse, varscan2
- SLC26A4 | c.1229C>T p.T410M | Missense Mutation (SNP) | VAF 102/350 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs111033220, CM981504; ClinVar: pathogenic; called by muse, mutect2, varscan2
- THRB | c.949G>A p.A317T | Missense Mutation (SNP) | VAF 36/203 reads (18%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.988); catalogued as rs121918690, CM153084, CM910364, COSV54982070; ClinVar: pathogenic; called by muse, mutect2, varscan2
- A1BG | c.545G>A p.C182Y | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54053182; called by muse, mutect2, varscan2
- AAAS | c.771del p.R258Gfs*33 | Frame Shift Del (DEL) | VAF 14/76 reads (18%) | catalogued as rs1184877278, CD067140; called by mutect2, pindel
- AANAT | c.457G>A p.V153M | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.856); catalogued as rs576095033, COSV51684152, COSV99166268; called by muse, mutect2, varscan2
- AARS2 | c.1064G>A p.R355H | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768992661, COSV55117239; called by muse, mutect2, varscan2
- ABCA12 | c.2683+1G>A p.X895_splice (on ENST00000272895 / NM_173076.3; = p.X577_splice on NM_015657.3) | Splice Site (SNP) | VAF 25/94 reads (27%) | catalogued as COSV55972854; called by muse, mutect2, varscan2
- ABCA13 | c.6179C>A p.P2060H | Missense Mutation (SNP) | VAF 24/112 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.296); catalogued as rs775473596, COSV70041956, COSV70042650; called by muse, mutect2, varscan2
- ABCA7 | c.1763G>A p.R588H | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.82); catalogued as COSV54029096; called by muse, mutect2, varscan2
- ABHD17A | c.298T>C p.S100P | Missense Mutation (SNP) | VAF 24/105 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.048); catalogued as COSV51751713; called by muse, mutect2, varscan2
- ABRAXAS2 | c.591dup p.D198* | Frame Shift Ins (INS) | VAF 94/454 reads (21%) | catalogued as rs1278087760; called by mutect2, pindel, varscan2
- AC005324.2 | c.1058G>A p.R353H | Missense Mutation (SNP) | VAF 55/257 reads (21%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.003); catalogued as COSV60888156; called by muse, mutect2, varscan2
- AC013489.1 | c.367C>T p.R123C | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.543); catalogued as rs749778687, COSV51553193; called by mutect2, varscan2
- AC100868.1 | c.949C>T p.R317C | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780723666, COSV99226895; called by mutect2, varscan2
- AC131160.1 | c.499C>T p.R167W | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs762841882, COSV57702021; called by muse, mutect2, varscan2
- ACACB | c.7060C>T p.H2354Y | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.572); catalogued as COSV100623301; called by muse, varscan2
- ACOT7 | c.253G>A p.A85T (on ENST00000377855 / NM_181864.3; = p.A75T on NM_007274.4) | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT tolerated (0.38); PolyPhen benign (0.097); catalogued as rs1314714440, COSV64111832; called by muse, mutect2, varscan2
- ACR | c.817G>A p.G273R | Missense Mutation (SNP) | VAF 36/148 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754872586, COSV53361817; called by muse, varscan2
- ACSBG2 | c.1219G>A p.E407K | Missense Mutation (SNP) | VAF 59/216 reads (27%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.679); catalogued as rs758992299, COSV53124024; called by muse, mutect2, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 68/133 reads (51%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ACVRL1 | c.139C>T p.R47W | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as rs768072967, COSV66360863; called by muse, mutect2, varscan2
- ADAMTS16 | c.673A>G p.T225A | Missense Mutation (SNP) | VAF 18/91 reads (20%) | SIFT tolerated (0.74); PolyPhen benign (0.007); catalogued as rs764487544, COSV56998073, COSV56999431; called by muse, mutect2, varscan2
- ADAMTS2 | c.3139C>T p.R1047C | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as rs758048360, COSV52388571; called by muse, mutect2, varscan2
- ADCY5 | c.1033G>A p.V345M | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV71901583; called by muse, mutect2, varscan2
- ADCY9 | c.3518C>T p.T1173M | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1371707087, COSV53572532; called by muse, mutect2, varscan2
- ADGRL1 | c.2921C>T p.P974L (on ENST00000340736 / NM_001008701.3; = p.P969L on NM_014921.5) | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV61566024, COSV61566384; called by muse, mutect2, varscan2
- ADGRL2 | c.3130C>A p.L1044M (on ENST00000370717 / NM_001366005.1; = p.L1031M on NM_012302.4) | Missense Mutation (SNP) | VAF 83/474 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV54685049; called by muse, mutect2, varscan2
- ADRA2A | c.217G>A p.V73M | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1185211608, COSV54529704; called by muse, mutect2, varscan2
- AGO4 | c.1847G>A p.R616Q | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.619); catalogued as rs754880287, COSV64616450; called by muse, mutect2, varscan2
- AHDC1 | c.4651G>A p.V1551M | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.866); catalogued as rs375725827; called by muse, mutect2, varscan2
- AHNAK2 | c.7297C>A p.P2433T | Missense Mutation (SNP) | VAF 21/148 reads (14%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.895); catalogued as COSV60927929; called by muse, varscan2
- AK9 | c.500C>T p.T167M | Missense Mutation (SNP) | VAF 52/221 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs374987709; called by muse, mutect2, varscan2
- AKAP6 | c.4252del p.E1418Kfs*19 | Frame Shift Del (DEL) | VAF 18/86 reads (21%) | catalogued as COSV99803400; called by mutect2, pindel, varscan2
- AKR1E2 | c.568C>T p.P190S | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs760750969, COSV53631699; called by muse, mutect2, varscan2
- AL136295.1 | c.1285C>T p.R429C | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.759); catalogued as rs748878938, COSV55781568; called by muse, mutect2, varscan2
- ALDOB | c.487G>A p.A163T | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); catalogued as rs17852652, COSV100878925; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ALK | c.1357C>T p.Q453* | Nonsense Mutation (SNP) | VAF 42/178 reads (24%) | catalogued as COSV101202694; called by muse, mutect2, varscan2
- ALPK2 | c.1568del p.K523Rfs*15 | Frame Shift Del (DEL) | VAF 34/169 reads (20%) | catalogued as rs1341338515; called by mutect2, pindel, varscan2
- ALPK3 | c.2642C>T p.A881V | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as rs375943296; called by muse, mutect2, varscan2
- ALPL | c.454C>T p.R152C | Missense Mutation (SNP) | VAF 39/108 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.025); catalogued as rs200621180, CM128799, COSV66380680; called by muse, mutect2, varscan2
- ANAPC1 | c.1859C>T p.T620M | Missense Mutation (SNP) | VAF 96/377 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.197); catalogued as rs144034109; called by muse, mutect2, varscan2
- ANGEL2 | c.950G>A p.R317Q | Missense Mutation (SNP) | VAF 41/173 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765456910, COSV64738158; called by muse, mutect2, varscan2
- ANGPT1 | c.1026G>T p.K342N | Missense Mutation (SNP) | VAF 25/137 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.112); catalogued as COSV52454364; called by muse, mutect2, varscan2
- ANK3 | c.8272G>A p.V2758I | Missense Mutation (SNP) | VAF 118/470 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.023); catalogued as rs150537210; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.3082C>T p.Q1028* | Nonsense Mutation (SNP) | VAF 52/291 reads (18%) | catalogued as COSV51856636; called by muse, mutect2, varscan2
- ANKRD11 | c.7840G>A p.A2614T | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56369876; called by muse, mutect2, varscan2
- ANKRD26 | c.2732C>T p.S911L | Missense Mutation (SNP) | VAF 74/297 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs373167535; called by muse, mutect2, varscan2
- ANKRD52 | c.520C>T p.R174W | Missense Mutation (SNP) | VAF 13/195 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99920971; called by muse, mutect2
- ANKS1B | c.3127A>G p.T1043A (on ENST00000547776 / NM_152788.4; = p.T209A on NM_020140.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 47/222 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.056); catalogued as COSV59123916; called by muse, mutect2, varscan2
- ANKS6 | c.2515C>T p.R839C | Missense Mutation (SNP) | VAF 28/117 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as rs753990621, COSV62051109; called by muse, mutect2, varscan2
- ANLN | c.207dup p.R70Tfs*4 | Frame Shift Ins (INS) | VAF 46/242 reads (19%) | catalogued as rs1232253883; called by mutect2, varscan2
- ANO2 | c.2657C>T p.P886L (on ENST00000356134 / NM_001278597.3; = p.P890L on NM_001278596.3) | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.02); catalogued as rs754149600, COSV59039805; called by muse, mutect2, varscan2
- AOC1 | c.1027G>A p.G343R | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.107); catalogued as rs774495004, COSV62870526; called by muse, mutect2, varscan2
- APBB2 | c.764C>T p.P255L | Missense Mutation (SNP) | VAF 91/369 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs144148235, COSV55960771; called by muse, mutect2, varscan2
- APOD | c.370G>A p.D124N | Missense Mutation (SNP) | VAF 17/157 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as rs201787147, COSV58402622; called by muse, mutect2, varscan2
- AQP6 | c.163G>A p.V55M | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.202); catalogued as rs369863737; called by muse, mutect2, varscan2
- ARFGAP3 | c.896del p.N299Mfs*22 | Frame Shift Del (DEL) | VAF 42/360 reads (12%) | catalogued as rs774441374, COSV54310368; called by mutect2, varscan2
- ARFGEF3 | c.1123C>T p.R375C | Missense Mutation (SNP) | VAF 82/306 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as rs140773391; called by muse, mutect2, varscan2
- ARHGAP21 | c.3923G>A p.R1308Q | Missense Mutation (SNP) | VAF 42/186 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.127); catalogued as rs1456876525, COSV57610212; called by muse, mutect2, varscan2
- ARHGAP22 | c.59G>A p.G20E | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.079); catalogued as rs1279162972, COSV99986051; called by muse, mutect2, varscan2
- ARHGEF2 | c.2513G>A p.R838Q (on ENST00000361247 / NM_001162383.2; = p.R810Q on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.953); catalogued as rs911479686, COSV58117299; called by muse, mutect2, varscan2
- ARHGEF39 | c.395G>A p.R132Q | Missense Mutation (SNP) | VAF 25/100 reads (25%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as rs994417788, COSV58398109; called by muse, mutect2, varscan2
- ARHGEF7 | c.2230G>A p.V744I (on ENST00000375741 / NM_001113511.2; = p.V723I on NM_145735.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.088); catalogued as rs1203337706, COSV54545070; called by muse, mutect2, varscan2
- ARID5B | c.1184G>A p.R395H | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99690455; called by muse, varscan2
- ARL8B | c.207C>A p.I69= | Splice Region (SNP) | VAF 30/134 reads (22%) | catalogued as COSV56579814; called by muse, varscan2
- ARMC5 | c.2072C>T p.P691L | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as rs201559372, COSV99192836; called by mutect2, varscan2
- ARNT2 | c.136C>T p.R46W | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs140468271, CM141147, COSV57583743; called by muse, mutect2, varscan2
- ARSB | c.1483G>A p.V495I | Missense Mutation (SNP) | VAF 63/264 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.215); catalogued as rs138643812, COSV53730252; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ARSD | c.260C>T p.P87L | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.593); catalogued as rs760931823, COSV54201976; called by muse, mutect2, varscan2
- ARSF | c.784C>T p.R262* | Nonsense Mutation (SNP) | VAF 39/139 reads (28%) | catalogued as rs200082842, COSV63840843; called by muse, mutect2, varscan2
- ARSJ | c.1292dup p.N431Kfs*53 | Frame Shift Ins (INS) | VAF 38/191 reads (20%) | catalogued as rs1562327720; called by mutect2, pindel, varscan2
- ARSJ | c.591del p.F197Lfs*54 | Frame Shift Del (DEL) | VAF 90/394 reads (23%) | catalogued as rs1269648295; called by mutect2, pindel, varscan2
- ASCC3 | c.489dup p.G164Wfs*2 | Frame Shift Ins (INS) | VAF 58/271 reads (21%) | catalogued as rs747570359; called by mutect2, varscan2
- ASPDH | c.199C>T p.R67C (on ENST00000389208 / NM_001114598.2; = p.R12C on NM_001024656.3) | Missense Mutation (SNP) | VAF 29/94 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as rs755585940, COSV65350684; called by muse, mutect2, varscan2
- ASRGL1 | c.646G>A p.V216I | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT tolerated (0.34); PolyPhen benign (0.05); catalogued as rs777549556, COSV57124197; called by muse, mutect2, varscan2
- ASXL2 | c.4157C>T p.A1386V | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.793); catalogued as rs780551383, COSV55466416; called by muse, mutect2, varscan2
- ATG9A | c.211A>G p.M71V | Missense Mutation (SNP) | VAF 22/101 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs757225337, COSV60135156; called by muse, mutect2
- ATP2B3 | c.792C>T p.G264= | Splice Region (SNP) | VAF 32/188 reads (17%) | catalogued as COSV54859235; called by muse, mutect2, varscan2
- ATP7B | c.3616G>A p.V1206M | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV54442677; called by muse, mutect2, varscan2
- AVPR1A | c.680C>T p.A227V | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs1475024151, COSV54547249; called by muse, mutect2, varscan2
- AWAT2 | c.299G>A p.R100H | Missense Mutation (SNP) | VAF 134/516 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs148056868, COSV52144385; called by muse, mutect2, varscan2
- AXIN1 | c.1116+1G>A p.X372_splice | Splice Site (SNP) | VAF 8/51 reads (16%) | catalogued as COSV51984731; called by muse, mutect2, varscan2
- AXIN2 | c.288_289del p.T97Ffs*43 | Frame Shift Del (DEL) | VAF 29/148 reads (20%) | catalogued as COSV61060188; called by mutect2, pindel, varscan2
- BCAN | c.320G>A p.R107H | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61259170; called by muse, mutect2, varscan2
- BCKDK | c.212C>T p.T71M | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.988); catalogued as COSV54893625; called by muse, mutect2
- BCL11B | c.2522G>A p.R841H (on ENST00000357195 / NM_001282237.2; = p.R770H on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61738715; called by muse, mutect2, varscan2
- BCL11B | c.779C>T p.T260M (on ENST00000357195 / NM_001282237.2; = p.T189M on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs756798054, COSV61738723; called by muse, mutect2, varscan2
- BET1L | c.241G>A p.G81R | Missense Mutation (SNP) | VAF 33/138 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.659); catalogued as rs201986208, COSV100254920; called by muse, mutect2, varscan2
- BICDL1 | c.463C>T p.R155* | Nonsense Mutation (SNP) | VAF 32/151 reads (21%) | catalogued as rs368843219; called by muse, mutect2, varscan2
- BOP1 | c.154G>A p.V52I | Missense Mutation (SNP) | VAF 45/153 reads (29%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.007); catalogued as rs782267874, COSV56639960; called by muse, mutect2, varscan2
- BPIFB6 | c.74G>A p.R25Q | Missense Mutation (SNP) | VAF 19/98 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); catalogued as rs148120627; called by muse, mutect2, varscan2
- BRAF | c.1328dup p.A444Cfs*9 (on ENST00000288602 / NM_001374244.1; = p.A404Cfs*9 on NM_004333.6 and 3 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 16/111 reads (14%) | catalogued as rs777474487; called by mutect2, varscan2
- BRINP3 | c.1793G>A p.R598Q | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.053); catalogued as rs757438144, COSV100819444, COSV66529448; called by muse, mutect2, varscan2
- BTBD3 | c.1171C>T p.R391C | Missense Mutation (SNP) | VAF 15/99 reads (15%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as rs930540638, COSV54778752; called by muse, mutect2, varscan2
- C15orf39 | c.1976C>T p.P659L | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); catalogued as rs147591499; called by muse, mutect2, varscan2
- C1orf94 | c.1469C>T p.A490V (on ENST00000488417 / NM_001134734.2; = p.A300V on NM_032884.5) | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.187); catalogued as rs760165855, COSV64915426; called by muse, mutect2, varscan2
- C20orf96 | c.10G>A p.V4I (on ENST00000360321 / NM_153269.3; = p.M1? on NM_080571.1) | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT tolerated (0.29); PolyPhen benign (0.014); catalogued as rs1238037682, COSV100826843; called by muse, mutect2, varscan2
- C2orf42 | c.1231C>T p.R411W | Missense Mutation (SNP) | VAF 24/124 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.024); catalogued as rs769259071, COSV52449977; called by muse, mutect2, varscan2
- C4orf50 | c.331G>A p.E111K (on ENST00000324058; = p.E1343K on NM_001364689.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.231); catalogued as rs1288076910, COSV100136175; called by muse, mutect2, varscan2
- CACHD1 | c.973C>T p.R325* | Nonsense Mutation (SNP) | VAF 84/312 reads (27%) | catalogued as COSV51551815; called by muse, mutect2, varscan2
- CACNA1C | c.5330G>A p.R1777H | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated, low confidence (0.2); PolyPhen probably damaging (0.976); catalogued as rs189719120, COSV59762242; called by mutect2, varscan2
- CACNA1F | c.3895C>T p.R1299* | Nonsense Mutation (SNP) | VAF 36/174 reads (21%) | catalogued as CM980294, COSV59906609; called by muse, mutect2
- CACNB1 | c.802C>T p.R268C | Missense Mutation (SNP) | VAF 23/123 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1239612747, COSV60000004; called by muse, mutect2, varscan2
- CALR | c.1231G>A p.G411S | Missense Mutation (SNP) | VAF 55/180 reads (31%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.039); catalogued as rs746740154, COSV100331103; called by muse, mutect2, varscan2
- CAMSAP2 | c.3041G>A p.R1014Q (on ENST00000236925 / NM_001297707.2; = p.R1003Q on NM_203459.3) | Missense Mutation (SNP) | VAF 44/200 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.951); catalogued as rs1299826864, COSV52671599; called by muse, mutect2, varscan2
- CARD11 | c.926G>A p.R309H | Missense Mutation (SNP) | VAF 16/101 reads (16%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.899); catalogued as rs778171630, COSV67801885; called by muse, mutect2, varscan2
- CARD19 | c.175C>T p.R59C | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.011); catalogued as rs201271055, COSV64936146; called by muse, mutect2, varscan2
- CASR | c.2455C>T p.R819C (on ENST00000490131; = p.R896C on NM_000388.4) | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.897); catalogued as rs749125441, COSV56140871; called by muse, mutect2, varscan2
- CAVIN1 | c.562G>A p.E188K | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.325); catalogued as COSV63812630; called by muse, mutect2, varscan2
- CBFA2T2 | c.1138C>T p.R380C | Missense Mutation (SNP) | VAF 22/136 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1442534272, COSV60797089; called by muse, mutect2, varscan2
- CBX5 | c.317del p.K106Rfs*31 | Frame Shift Del (DEL) | VAF 44/212 reads (21%) | catalogued as rs780649799; called by mutect2, varscan2
- CCAR1 | c.2150G>A p.R717Q | Missense Mutation (SNP) | VAF 33/140 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs1174554212, COSV56273591; called by muse, mutect2, varscan2
- CCDC116 | c.1457G>A p.R486H | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs967272795, COSV53039204, COSV99489292; called by muse, mutect2, varscan2
- CCDC146 | c.1844C>T p.T615M | Missense Mutation (SNP) | VAF 39/151 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99593142; called by muse, mutect2, varscan2
- CCDC151 | c.1777C>T p.R593W | Missense Mutation (SNP) | VAF 28/118 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.941); catalogued as COSV62699035; called by muse, mutect2, varscan2
- CCDC171 | c.920G>A p.R307Q | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.027); catalogued as rs921911022, COSV52650900; called by muse, mutect2, varscan2
- CCDC77 | c.143G>A p.R48H | Missense Mutation (SNP) | VAF 29/109 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs200513629; called by muse, mutect2, varscan2
- CCDC85A | c.1432C>T p.R478* | Nonsense Mutation (SNP) | VAF 29/117 reads (25%) | catalogued as rs533730078, COSV68154970; called by muse, mutect2, varscan2
- CCER1 | c.704C>T p.A235V | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.034); catalogued as COSV62645917; called by muse, mutect2, varscan2
- CCNA1 | c.1075G>A p.V359I | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT tolerated (0.28); PolyPhen benign (0.005); catalogued as rs748235047, COSV55221766; called by muse, mutect2, varscan2
- CD180 | c.1474C>T p.L492F | Missense Mutation (SNP) | VAF 36/162 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs766019282, COSV56519490; called by muse, mutect2, varscan2
- CD8B | c.521G>A p.G174D | Missense Mutation (SNP) | VAF 86/378 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.381); catalogued as COSV58928050; called by muse, mutect2, varscan2
- CDC14A | c.375del p.Y126Ifs*64 | Frame Shift Del (DEL) | VAF 43/245 reads (18%) | catalogued as rs773911500; called by mutect2, pindel, varscan2
- CDC20B | c.1279C>T p.R427C | Missense Mutation (SNP) | VAF 46/245 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs142234339, COSV99697054; called by muse, mutect2, varscan2
- CDC42EP4 | c.508G>A p.A170T | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs375486831; called by muse, mutect2, varscan2
- CDCA4 | c.67G>A p.G23S | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.206); catalogued as rs768754038, COSV60316116; called by mutect2, varscan2
- CDH2 | c.2153C>T p.A718V | Missense Mutation (SNP) | VAF 43/158 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.369); catalogued as rs140836073; called by muse, mutect2, varscan2
- CDKN2C | c.129G>T p.Q43H | Missense Mutation (SNP) | VAF 17/117 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52955778; called by muse, mutect2, varscan2
- CEACAM3 | c.619G>A p.A207T | Missense Mutation (SNP) | VAF 26/138 reads (19%) | SIFT tolerated (0.35); PolyPhen benign (0.031); catalogued as COSV55763092; called by muse, mutect2, varscan2
- CELA3A | c.628C>T p.R210C | Missense Mutation (SNP) | VAF 31/111 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.047); catalogued as rs149807589; called by muse, mutect2, varscan2
- CELSR2 | c.6511G>A p.V2171I | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT tolerated (0.48); PolyPhen benign (0.209); catalogued as rs760959194, COSV54778421, COSV99603750; called by muse, mutect2, varscan2
- CENPF | c.6310G>A p.A2104T | Missense Mutation (SNP) | VAF 28/87 reads (32%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.784); catalogued as rs756126833, COSV65278490; called by muse, mutect2, varscan2
- CEP104 | c.685C>T p.R229C | Missense Mutation (SNP) | VAF 107/419 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.034); catalogued as rs751813032, COSV65512798; called by muse, mutect2, varscan2
- CEP135 | c.1919C>T p.S640L | Missense Mutation (SNP) | VAF 109/436 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.017); catalogued as rs772012146, COSV57258799; called by muse, mutect2, varscan2
- CEP170 | c.1349C>T p.S450L | Missense Mutation (SNP) | VAF 127/633 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.035); catalogued as rs1314069652, COSV60513676; called by muse, mutect2, varscan2
- CEP78 | c.1178G>A p.R393H (on ENST00000424347 / NM_001349840.2; = p.R394H on NM_032171.3) | Missense Mutation (SNP) | VAF 9/200 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1018373694, COSV52845535; called by muse, mutect2
- CEP89 | c.1373G>A p.R458H | Missense Mutation (SNP) | VAF 23/127 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs766858182, COSV59866203; called by muse, mutect2, varscan2
- CERS4 | c.227G>T p.R76M | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.28); PolyPhen benign (0.113); catalogued as COSV52168113; called by muse, mutect2, varscan2
- CES2 | c.1574C>T p.A525V | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.031); catalogued as rs753837525, COSV57697016; called by mutect2, varscan2
- CFAP251 | c.620_621del p.E207Gfs*35 | Frame Shift Del (DEL) | VAF 26/140 reads (19%) | catalogued as rs1447479840; called by pindel, varscan2
- CFAP299 | c.245C>T p.T82M | Missense Mutation (SNP) | VAF 72/266 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.541); catalogued as rs765782959, COSV63872319; called by muse, mutect2, varscan2
- CHAF1A | c.106C>T p.R36C | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs374615768; called by muse, mutect2, varscan2
- CHD1 | c.269G>A p.S90N | Missense Mutation (SNP) | VAF 31/111 reads (28%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV99399909; called by muse, mutect2, varscan2
- CHD2 | c.4969T>C p.W1657R | Missense Mutation (SNP) | VAF 19/105 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV67711029; called by muse, mutect2, varscan2
- CHD8 | c.3389G>A p.R1130H (on ENST00000646647 / NM_001170629.2; = p.R851H on NM_020920.4) | Missense Mutation (SNP) | VAF 47/199 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.034); catalogued as rs765025620, COSV67872377; called by muse, mutect2, varscan2
- CHD8 | c.2263C>T p.P755S (on ENST00000646647 / NM_001170629.2; = p.P476S on NM_020920.4) | Missense Mutation (SNP) | VAF 54/223 reads (24%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.531); catalogued as COSV67872381; called by muse, mutect2, varscan2
- CHML | c.1207C>T p.R403C | Missense Mutation (SNP) | VAF 31/133 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.497); catalogued as rs762564140, COSV59364080; called by muse, mutect2, varscan2
- CHMP1A | c.211G>A p.A71T | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.164); catalogued as rs1263980813, COSV53684387; called by muse, mutect2, varscan2
- CILP | c.1342C>T p.R448C | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.296); catalogued as rs201015610, COSV56025993; called by muse, mutect2, varscan2
- CIZ1 | c.556C>T p.R186W | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.947); catalogued as rs141376660, COSV52974109; called by muse, mutect2, varscan2
- CLCA4 | c.1718C>T p.A573V | Missense Mutation (SNP) | VAF 27/106 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.012); catalogued as rs778796052, COSV55367864; called by muse, mutect2, varscan2
- CLDN19 | c.242G>A p.R81Q | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs901442993, COSV56418825; called by muse, mutect2, varscan2
- CLEC16A | c.2161G>A p.G721S | Missense Mutation (SNP) | VAF 54/238 reads (23%) | SIFT tolerated (0.74); PolyPhen possibly damaging (0.591); catalogued as rs202190195, COSV55491271, COSV99901425; called by muse, mutect2, varscan2
- CLPP | c.646_647del p.S216Pfs*37 | Frame Shift Del (DEL) | VAF 24/110 reads (22%) | catalogued as rs775742931; called by pindel, varscan2
- CLPX | c.1669C>T p.R557* | Nonsense Mutation (SNP) | VAF 43/192 reads (22%) | catalogued as rs773190880, COSV55646258; called by muse, mutect2, varscan2
- CLUAP1 | c.49G>T p.G17* | Nonsense Mutation (SNP) | VAF 88/361 reads (24%) | catalogued as COSV58894817; called by muse, mutect2, varscan2
- CLUH | c.1678C>T p.R560C (on ENST00000435359; = p.R598C on NM_015229.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV70927884; called by muse, mutect2, varscan2
- CMTM3 | c.460G>A p.V154M | Missense Mutation (SNP) | VAF 59/261 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.127); catalogued as rs777705777, COSV58063311; called by muse, mutect2, varscan2
- CNGB1 | c.803C>T p.P268L | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs369288085; called by muse, mutect2, varscan2
- CNPY2 | c.86G>A p.G29E | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV56265062; called by muse, mutect2, varscan2
- CNR1 | c.479C>T p.A160V | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759310920, COSV62987756; called by muse, mutect2, varscan2
- COBLL1 | c.2834del p.L945Cfs*12 (on ENST00000392717; = p.L907Cfs*12 on NM_014900.5) | Frame Shift Del (DEL) | VAF 28/94 reads (30%) | catalogued as rs374805044; called by mutect2, varscan2
- COG6 | c.1961C>T p.T654M | Missense Mutation (SNP) | VAF 38/189 reads (20%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.537); catalogued as rs747232819, COSV62997673; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL12A1 | c.5729C>A p.T1910N | Missense Mutation (SNP) | VAF 63/293 reads (22%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.942); catalogued as COSV59405755; called by muse, mutect2, varscan2
- COL18A1 | c.3181G>A p.V1061M (on ENST00000359759 / NM_130444.3; = p.V826M on NM_030582.4) | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT tolerated (0.43); PolyPhen benign (0.005); catalogued as rs371970491, COSV60586197; called by muse, mutect2, varscan2
- COL25A1 | c.1569G>T p.Q523H | Missense Mutation (SNP) | VAF 28/149 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.012); catalogued as COSV67655863; called by muse, mutect2, varscan2
- COL27A1 | c.2725G>A p.E909K | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1327419316, COSV61930114; called by muse, mutect2, varscan2
- COL3A1 | c.1714C>T p.R572* | Nonsense Mutation (SNP) | VAF 54/237 reads (23%) | catalogued as rs572097661, COSV58595344; called by muse, mutect2, varscan2
- COL4A6 | c.1562G>A p.G521E | Missense Mutation (SNP) | VAF 29/181 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV57875512; called by muse, mutect2, varscan2
- COL7A1 | c.5441G>A p.R1814H | Missense Mutation (SNP) | VAF 24/103 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs756258247, COSV60392875, COSV60397289; called by muse, mutect2, varscan2
- COLGALT1 | c.1340G>A p.R447H | Missense Mutation (SNP) | VAF 52/194 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs774477102, COSV53111279; called by muse, mutect2, varscan2
- COMMD9 | c.551G>A p.G184D | Missense Mutation (SNP) | VAF 36/168 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99661373; called by muse, varscan2
- COPA | c.1255G>A p.V419I | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.56); PolyPhen benign (0.113); catalogued as rs750819605, COSV99616808; called by mutect2, varscan2
- COPS6 | c.607G>A p.V203I | Missense Mutation (SNP) | VAF 31/176 reads (18%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.596); catalogued as COSV100385164; called by muse, mutect2, varscan2
- CPZ | c.550C>T p.R184C (on ENST00000360986 / NM_001014447.3; = p.R173C on NM_003652.3) | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.634); catalogued as rs149059553; called by muse, varscan2
- CREB3L3 | c.506C>T p.P169L | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs372036104; called by muse, mutect2, varscan2
- CRTC2 | c.1316C>T p.A439V | Missense Mutation (SNP) | VAF 29/124 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs779135391, COSV100339356; called by muse, mutect2, varscan2
- CRY2 | c.935G>A p.R312Q | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1192902527, COSV69889249; called by muse, mutect2, varscan2
- CTCF | c.832C>T p.R278C | Missense Mutation (SNP) | VAF 50/210 reads (24%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.985); catalogued as rs1266478000, COSV50479453; called by muse, mutect2, varscan2
- CTDP1 | c.2420C>T p.A807V | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.99); PolyPhen benign (0.005); catalogued as rs777446741, COSV50002993; called by mutect2, varscan2
- CTSW | c.577G>A p.G193S | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs377646629, COSV57173268; called by muse, mutect2, varscan2
- CUL3 | c.458G>A p.R153H | Missense Mutation (SNP) | VAF 47/183 reads (26%) | SIFT tolerated (0.28); PolyPhen benign (0.185); catalogued as rs972626651, COSV52369309; called by muse, mutect2, varscan2
- CUL9 | c.2252C>T p.A751V | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.031); catalogued as rs953476329, COSV52733223; called by muse, mutect2, varscan2
- CUX2 | c.711T>A p.D237E | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.012); catalogued as rs1470202335, COSV99920758; called by muse, mutect2, varscan2
- CXXC1 | c.1498C>T p.R500C | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53276526; called by muse, mutect2, varscan2
- CYLC1 | c.57A>C p.P19= | Splice Region (SNP) | VAF 30/987 reads (3%) | catalogued as COSV100255499; called by muse, mutect2
- CYP2D6 | c.1178C>T p.T393M | Missense Mutation (SNP) | VAF 79/536 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs757030056, COSV62244775; called by muse, mutect2, varscan2
- CYP2W1 | c.194C>T p.P65L | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); catalogued as rs890133451, COSV58269269; called by muse, varscan2
- CYP3A7 | c.652C>T p.P218S | Missense Mutation (SNP) | VAF 63/259 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.184); catalogued as COSV60483106; called by muse, mutect2, varscan2
- CYP4F8 | c.1064G>A p.R355Q | Missense Mutation (SNP) | VAF 26/146 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.863); catalogued as rs750213680, COSV100358243; called by muse, mutect2, varscan2
- DAPK3 | c.295G>A p.G99R | Missense Mutation (SNP) | VAF 29/123 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1446173155, COSV56664654; called by muse, mutect2, varscan2
- DCAKD | c.463G>A p.A155T | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs760941957, COSV60832353; called by muse, mutect2, varscan2
- DCHS1 | c.8306C>T p.A2769V | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.539); catalogued as rs200122562, COSV100197750; called by mutect2, varscan2
- DCST2 | c.1472G>A p.R491H | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.3); PolyPhen benign (0.005); catalogued as rs140460207; called by muse, mutect2, varscan2
- DDX27 | c.2072del p.K691Rfs*4 | Frame Shift Del (DEL) | VAF 23/88 reads (26%) | catalogued as rs766714372; called by mutect2, varscan2
- DDX51 | c.1793G>A p.R598H | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750785272, COSV100223205; called by muse, varscan2
- DDX54 | c.1738G>A p.A580T | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated (0.28); PolyPhen benign (0.009); catalogued as rs371172279, COSV100014204; called by mutect2, varscan2
- DDX60L | c.3721G>A p.A1241T | Missense Mutation (SNP) | VAF 57/251 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.905); catalogued as COSV52720579; called by muse, mutect2, varscan2
- DEFB113 | c.116G>A p.R39H | Missense Mutation (SNP) | VAF 67/280 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.105); catalogued as rs373794670; called by muse, mutect2, varscan2
- DGCR2 | c.1124G>A p.R375H | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs766794546, COSV54221214; called by muse, mutect2, varscan2
- DGCR2 | c.544C>T p.R182C | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.003); catalogued as rs747457352, COSV54221229; called by muse, mutect2, varscan2
- DHRS2 | c.164G>A p.R55H | Missense Mutation (SNP) | VAF 46/195 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs149593009; called by muse, mutect2, varscan2
- DMWD | c.1786C>T p.L596F | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV52181746; called by muse, mutect2, varscan2
- DNAH10 | c.1258G>A p.V420M (on ENST00000409039; = p.V359M on NM_207437.3) | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.265); catalogued as rs1403614920, COSV68990676; called by muse, mutect2, varscan2
- DNAH10 | c.5906T>C p.L1969P (on ENST00000409039; = p.L1908P on NM_207437.3) | Missense Mutation (SNP) | VAF 63/289 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV69000007; called by muse, mutect2
- DNAH11 | c.1409G>A p.R470H | Missense Mutation (SNP) | VAF 84/426 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.077); catalogued as rs775108833, COSV60955790; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAH2 | c.514C>T p.L172F | Missense Mutation (SNP) | VAF 23/85 reads (27%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.454); catalogued as COSV50019471; called by muse, mutect2, varscan2
- DNAH6 | c.1367C>T p.T456M | Missense Mutation (SNP) | VAF 30/140 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.107); catalogued as rs758124840, COSV52859949; called by muse, mutect2, varscan2
- DNAH9 | c.7969G>A p.A2657T | Missense Mutation (SNP) | VAF 46/175 reads (26%) | SIFT tolerated (0.38); PolyPhen benign (0.009); catalogued as rs765369355, COSV52351935; called by muse, mutect2, varscan2
- DNAI2 | c.43G>A p.G15R | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs758997612, COSV56756577; ClinVar: likely benign; called by muse, mutect2, varscan2
- DNAI4 | c.551C>A p.T184K | Missense Mutation (SNP) | VAF 19/278 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.075); catalogued as COSV100925241; called by muse, mutect2
- DNAJB12 | c.1009G>A p.E337K (on ENST00000338820; = p.E303K on NM_017626.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/134 reads (19%) | SIFT tolerated (0.96); PolyPhen benign (0.012); catalogued as rs202084225, COSV100123815; called by muse, mutect2, varscan2
- DNM3 | c.292C>T p.R98C | Missense Mutation (SNP) | VAF 20/97 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs527384140, COSV62455336; called by muse, mutect2, varscan2
- DNMT3B | c.1846G>A p.V616M | Missense Mutation (SNP) | VAF 31/154 reads (20%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.593); catalogued as rs754182982, COSV52415403; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DOK3 | c.970C>T p.L324F | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.799); catalogued as COSV100467443; called by muse, mutect2, varscan2
- DOP1B | c.4025G>A p.R1342Q | Missense Mutation (SNP) | VAF 17/126 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.096); catalogued as rs752694158; called by muse, mutect2, varscan2
- DPP8 | c.493G>A p.G165R (on ENST00000341861 / NM_001320875.2; = p.G149R on NM_017743.6) | Missense Mutation (SNP) | VAF 55/284 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.387); catalogued as rs1432951432, COSV55681000; called by muse, mutect2, varscan2
- DRAM2 | c.188C>T p.A63V | Missense Mutation (SNP) | VAF 98/450 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.251); catalogued as rs145044841, COSV54415436; called by muse, varscan2
- DRAM2 | c.134A>G p.D45G | Missense Mutation (SNP) | VAF 84/397 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99713479; called by muse, varscan2
- DST | c.1324C>T p.R442C (on ENST00000361203 / NM_001374722.1; = p.R116C on NM_001723.6) | Missense Mutation (SNP) | VAF 44/181 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as rs377406538; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DTNB | c.1150C>T p.R384C | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.513); catalogued as rs149194865, COSV56483208; called by muse, mutect2, varscan2
- DUSP22 | c.68C>T p.A23V | Missense Mutation (SNP) | VAF 20/280 reads (7%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs147959810; called by muse, mutect2
- DVL1 | c.227G>A p.R76H | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs750153032, COSV66680282; called by muse, mutect2
- DYNC2I1 | c.1000G>A p.E334K | Missense Mutation (SNP) | VAF 39/150 reads (26%) | SIFT tolerated (0.35); PolyPhen benign (0.028); catalogued as rs201126878, COSV68106818; called by muse, mutect2, varscan2
- E4F1 | c.1474C>T p.R492C | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs142977286; called by muse, mutect2, varscan2
- EEF2K | c.586del p.E196Rfs*22 | Frame Shift Del (DEL) | VAF 8/54 reads (15%) | catalogued as rs1567276794; called by mutect2, pindel, varscan2
- EGR2 | c.560C>T p.A187V | Missense Mutation (SNP) | VAF 27/121 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.179); catalogued as rs372491511; called by muse, mutect2, varscan2
- EIF2AK3 | c.1897C>T p.R633W | Missense Mutation (SNP) | VAF 27/120 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748318874, CM097402, COSV57545397; called by muse, mutect2, varscan2
- ELP5 | c.626G>A p.R209H | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as rs996052635, COSV100598249; called by muse, mutect2, varscan2
- EOGT | c.575G>A p.R192H | Missense Mutation (SNP) | VAF 17/103 reads (17%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs138697363; called by muse, mutect2, varscan2
- EPHB1 | c.2247C>A p.N749K | Missense Mutation (SNP) | VAF 61/224 reads (27%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as COSV67657003, COSV67668981; called by muse, mutect2, varscan2
- EPS8 | c.1300C>T p.R434C | Missense Mutation (SNP) | VAF 94/373 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.125); catalogued as rs147224631; called by muse, mutect2, varscan2
- ERGIC3 | c.1148C>T p.T383M | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as rs201180063, COSV53414813; called by muse, mutect2, varscan2
- ESRRB | c.562C>T p.R188W | Missense Mutation (SNP) | VAF 38/138 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs370122804; called by muse, varscan2
- ESS2 | c.112C>A p.L38M | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.592); catalogued as COSV50082676; called by muse, mutect2, varscan2
- ETNK2 | c.628G>A p.E210K | Missense Mutation (SNP) | VAF 39/191 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.013); catalogued as rs768590671, COSV65821236; called by muse, mutect2, varscan2
- EVA1C | c.1172C>T p.S391L | Missense Mutation (SNP) | VAF 33/102 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.038); catalogued as rs779127738, COSV55826368; called by muse, mutect2, varscan2
- EXO1 | c.1862C>T p.T621M | Missense Mutation (SNP) | VAF 31/139 reads (22%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.72); catalogued as rs367935074; called by muse, mutect2, varscan2
- F2R | c.527G>A p.R176H | Missense Mutation (SNP) | VAF 46/283 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs752231723, COSV100058675, COSV100058731, COSV59928497; called by muse, mutect2, varscan2
- F8 | c.6325C>T p.R2109C | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1475665992, CM001998, COSV100811770, COSV100811958; called by muse, mutect2, varscan2
- FADS3 | c.1267G>A p.A423T | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1291657467, COSV53880151; called by muse, mutect2, varscan2
- FAM161A | c.557C>A p.P186H | Missense Mutation (SNP) | VAF 61/368 reads (17%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.461); catalogued as COSV56768396; called by muse, mutect2, varscan2
- FAM199X | c.169G>A p.D57N | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.275); catalogued as COSV72419991; called by muse, mutect2, varscan2
- FAM47B | c.506G>A p.R169Q | Missense Mutation (SNP) | VAF 34/113 reads (30%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as rs748787682, COSV61454213; called by muse, mutect2, varscan2
- FAM50A | c.550C>T p.R184W | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs782214551, COSV99341211; called by mutect2, varscan2
- FBLN7 | c.1279G>A p.V427M | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.605); catalogued as rs749054176, COSV55616109; called by muse, mutect2, varscan2
- FBN1 | c.608T>C p.V203A | Missense Mutation (SNP) | VAF 24/102 reads (24%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.989); catalogued as COSV57328078; called by muse, mutect2, varscan2
- FBXW10 | c.2641C>T p.R881* | Nonsense Mutation (SNP) | VAF 55/272 reads (20%) | catalogued as rs147519900; called by muse, mutect2, varscan2
- FCHO1 | c.454C>T p.R152W | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs970252335, COSV99405919; called by muse, mutect2, varscan2
- FCHO2 | c.44del p.N15Ifs*11 | Frame Shift Del (DEL) | VAF 86/424 reads (20%) | catalogued as rs768979093, COSV55110370; called by mutect2, pindel, varscan2
- FEM1B | c.662C>T p.T221M | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60989538; called by muse, mutect2, varscan2
- FGD5 | c.961G>A p.A321T | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs546389054, COSV53244199; called by muse, mutect2, varscan2
- FGFBP1 | c.78del p.V27* | Frame Shift Del (DEL) | VAF 64/272 reads (24%) | catalogued as rs144178676; called by mutect2, varscan2
- FHDC1 | c.3091C>T p.R1031C | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.057); catalogued as COSV52602558, COSV99471179; called by muse, mutect2, varscan2
- FITM2 | c.253G>A p.G85S | Missense Mutation (SNP) | VAF 17/81 reads (21%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.593); catalogued as rs771219892, COSV67679095, COSV67679447; called by muse, mutect2, varscan2
- FKBP8 | c.865C>T p.R289C (on ENST00000222308 / NM_001308373.2; = p.R290C on NM_012181.5) | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.141); catalogued as rs758585209, COSV55893728; called by muse, mutect2, varscan2
- FLNC | c.7921C>T p.R2641W | Missense Mutation (SNP) | VAF 34/158 reads (22%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.953); catalogued as rs750629528, COSV50800240; called by muse, mutect2, varscan2
- FMO4 | c.556C>T p.R186C | Missense Mutation (SNP) | VAF 29/164 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs767244751, COSV63001841; called by muse, mutect2, varscan2
- FNTA | c.302A>T p.D101V | Missense Mutation (SNP) | VAF 52/210 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.775); catalogued as COSV56491388; called by muse, mutect2, varscan2
- FPGS | c.1553G>A p.S518N | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.195); catalogued as COSV61228621, COSV61229325; called by muse, mutect2, varscan2
- FREM1 | c.3592G>A p.D1198N | Missense Mutation (SNP) | VAF 92/330 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs772523599, COSV66528833; called by muse, mutect2, varscan2
- FREM2 | c.4543C>T p.R1515C | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.655); catalogued as rs765714454, COSV54849572; called by muse, varscan2
- FRMD5 | c.946C>T p.R316W | Missense Mutation (SNP) | VAF 39/167 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs535767161, COSV68724935; called by muse, mutect2, varscan2
- FTSJ3 | c.526C>T p.R176C | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as rs779455824, COSV100037508, COSV59563810; called by muse, mutect2, varscan2
- FUT2 | c.212G>A p.R71H | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs374416675; called by muse, mutect2, varscan2
- FYN | c.569G>A p.R190H | Missense Mutation (SNP) | VAF 32/149 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as rs756342493, COSV57611357; called by muse, mutect2, varscan2
- FZD7 | c.937G>A p.A313T | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.046); catalogued as rs1458457825, COSV53809554; called by muse, mutect2, varscan2
- GALNT5 | c.1682G>A p.R561H | Missense Mutation (SNP) | VAF 72/368 reads (20%) | SIFT tolerated (0.82); PolyPhen benign (0.041); catalogued as rs202106852, COSV52039905; called by muse, mutect2, varscan2
- GAMT | c.473G>A p.R158H | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as rs750195151, COSV52041001; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GART | c.2420del p.K807Rfs*7 | Frame Shift Del (DEL) | VAF 32/95 reads (34%) | catalogued as rs758551787; called by mutect2, varscan2
- GBP6 | c.1655C>T p.T552M | Missense Mutation (SNP) | VAF 57/236 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as rs369535516; called by muse, mutect2, varscan2
- GCDH | c.1228G>A p.V410M | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs760155287, CM155774, COSV53368342; called by muse, mutect2, varscan2
- GCN1 | c.5399C>T p.A1800V | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs371797364; called by muse, mutect2, varscan2
- GGA3 | c.467T>C p.L156P (on ENST00000537686 / NM_138619.4; = p.L123P on NM_014001.5) | Missense Mutation (SNP) | VAF 46/127 reads (36%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.961); catalogued as rs778050483, COSV99822355; called by muse, mutect2
- GIGYF2 | c.3884C>T p.T1295M | Missense Mutation (SNP) | VAF 46/178 reads (26%) | SIFT tolerated (0.28); PolyPhen benign (0.067); catalogued as rs751053780, COSV65254734; called by muse, mutect2, varscan2
- GLA | c.309A>C p.E103D | Missense Mutation (SNP) | VAF 34/174 reads (20%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV54510399; called by muse, mutect2, varscan2
- GMDS | c.166C>T p.R56W | Missense Mutation (SNP) | VAF 35/143 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs771650335, COSV66440802; called by muse, mutect2, varscan2
- GMPR | c.110C>T p.T37M | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.673); catalogued as rs138267551; called by muse, mutect2, varscan2
- GOLGA3 | c.2063C>T p.A688V | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT tolerated (0.26); PolyPhen benign (0.036); catalogued as rs199619272, COSV52639306; called by muse, mutect2, varscan2
- GOLGB1 | c.9658G>A p.V3220I | Missense Mutation (SNP) | VAF 27/97 reads (28%) | SIFT tolerated (0.46); PolyPhen benign (0.019); catalogued as rs1313335521, COSV58859746; called by muse, mutect2, varscan2
- GP1BA | c.1922G>A p.S641N | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0); catalogued as rs913991352, COSV99851183; called by mutect2, varscan2
- GPAM | c.304C>T p.R102C | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs767395257, COSV62082407; called by muse, mutect2, varscan2
- GPI | c.247C>T p.R83W | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.673); catalogued as rs983725326, CM940877, COSV62894774; called by muse, mutect2, varscan2
- GPR151 | c.725A>G p.Q242R | Missense Mutation (SNP) | VAF 63/321 reads (20%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.971); catalogued as COSV57041146; called by muse, mutect2, varscan2
- GPR75 | c.1546C>T p.H516Y | Missense Mutation (SNP) | VAF 49/220 reads (22%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.123); catalogued as COSV61825774; called by muse, mutect2, varscan2
- GPR75 | c.904C>T p.R302* | Nonsense Mutation (SNP) | VAF 50/152 reads (33%) | catalogued as rs376986894; called by muse, mutect2, varscan2
- GREB1 | c.2915C>T p.A972V | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.215); catalogued as COSV52194896; called by muse, mutect2, varscan2
- GRIK1 | c.2673del p.K891Nfs*6 (on ENST00000327783 / NM_001330994.2; = p.K876Nfs*6 on NM_001330993.2) | Frame Shift Del (DEL) | VAF 80/388 reads (21%) | catalogued as rs747093705; called by mutect2, varscan2
- GRSF1 | c.1348C>T p.H450Y | Missense Mutation (SNP) | VAF 62/205 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.72); catalogued as COSV54656978, COSV99635601; called by muse, mutect2, varscan2
- GSE1 | c.2345C>T p.P782L | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs148817156; called by muse, varscan2
- GTF3C1 | c.4978C>T p.R1660C | Missense Mutation (SNP) | VAF 44/197 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs758357323, COSV62243658, COSV62244346; called by muse, mutect2, varscan2
- H2BC8 | c.121T>C p.Y41H | Missense Mutation (SNP) | VAF 63/286 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV55127671; called by muse, mutect2, varscan2
- H3C6 | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 32/199 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.102); catalogued as rs776406667, COSV64519844; called by muse, mutect2, varscan2
- HCFC1 | c.410G>A p.R137Q | Missense Mutation (SNP) | VAF 36/124 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60076791; called by muse, mutect2, varscan2
- HCN4 | c.1474G>A p.V492I | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.997); catalogued as rs772144022, COSV56086732; called by mutect2, varscan2
- HDAC7 | c.109C>A p.L37M (on ENST00000427332; = p.L76M on NM_015401.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.687); catalogued as COSV99316922; called by muse, mutect2
- HELLS | c.1025C>T p.A342V | Missense Mutation (SNP) | VAF 48/184 reads (26%) | SIFT tolerated (0.39); PolyPhen benign (0.007); catalogued as rs770460162, COSV53300674; called by muse, mutect2, varscan2
- HELZ2 | c.4846G>A p.E1616K (on ENST00000467148 / NM_001037335.2; = p.E1047K on NM_033405.3) | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.91); PolyPhen benign (0.051); catalogued as rs776067170, COSV101427624; called by muse, mutect2
- HERC2 | c.10805C>T p.S3602L | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.062); catalogued as rs1427631845, COSV55345750; called by muse, mutect2
- HEYL | c.781G>A p.A261T | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0.267); catalogued as rs752690094, COSV100865343; called by muse, mutect2, varscan2
- HLA-DQB1 | c.515C>T p.A172V | Missense Mutation (SNP) | VAF 36/101 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.018); catalogued as COSV66574381; called by muse, mutect2
- HP | c.1081G>A p.V361I | Missense Mutation (SNP) | VAF 44/211 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as rs371501447; called by muse, mutect2, varscan2
- HRC | c.487G>A p.E163K | Missense Mutation (SNP) | VAF 69/318 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.351); catalogued as rs751086318, COSV53256902; called by mutect2, varscan2
- HS3ST6 | c.817G>A p.V273I | Missense Mutation (SNP) | VAF 35/100 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.104); catalogued as rs200947593; called by muse, mutect2, varscan2
- HS6ST2 | c.923G>A p.R308H | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.462); catalogued as COSV63717542; called by muse, mutect2, varscan2
- HSD17B4 | c.1493G>A p.R498Q (on ENST00000414835 / NM_001199291.3; = p.R473Q on NM_000414.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 32/108 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.217); catalogued as rs901553037, COSV56336000; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HUWE1 | c.4414A>G p.N1472D | Missense Mutation (SNP) | VAF 54/308 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.76); catalogued as COSV53361494; called by muse, mutect2, varscan2
- IARS2 | c.2984C>T p.A995V | Missense Mutation (SNP) | VAF 40/199 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.13); catalogued as rs779950037, COSV56963454; called by muse, mutect2, varscan2
- IFT140 | c.2426G>A p.R809H | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs780661065, COSV54154445; called by muse, mutect2, varscan2
- IFT57 | c.733C>T p.R245C | Missense Mutation (SNP) | VAF 62/215 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs371129548; called by muse, mutect2, varscan2
- IGFBP7 | c.498del p.K167Rfs*13 | Frame Shift Del (DEL) | VAF 7/36 reads (19%) | catalogued as rs765398170; called by mutect2, pindel, varscan2
- IGSF22 | c.647G>A p.R216Q | Missense Mutation (SNP) | VAF 48/201 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs745665365, COSV60037987; called by muse, mutect2, varscan2
- IGSF9B | c.1303G>A p.G435S | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs1440992717, COSV58071899; called by muse, mutect2, varscan2
- IL10RA | c.302G>A p.R101Q | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs372372851; ClinVar: uncertain significance; called by muse, varscan2
- IL1R1 | c.1628G>A p.R543Q | Missense Mutation (SNP) | VAF 31/114 reads (27%) | SIFT tolerated (0.6); PolyPhen benign (0.024); catalogued as rs749524190, COSV52105792; called by muse, mutect2, varscan2
- ILVBL | c.1129C>T p.R377W | Missense Mutation (SNP) | VAF 19/108 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.959); catalogued as rs142150131, COSV54622142; called by muse, mutect2, varscan2
- INCENP | c.11C>T p.T4M | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.058); catalogued as rs779937744, COSV53920305; called by muse, mutect2, varscan2
- INHBE | c.760G>A p.V254I | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT tolerated (0.28); PolyPhen benign (0.23); catalogued as rs759206435, COSV56988142; called by muse, mutect2, varscan2
- INPP4A | c.701G>A p.R234Q | Missense Mutation (SNP) | VAF 40/162 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1179261857, COSV50792214; called by muse, varscan2
- INPP5E | c.1346C>A p.P449H | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65497126; called by muse, mutect2, varscan2
- INSRR | c.899G>T p.C300F | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.452); catalogued as rs1286518795, COSV63876733; called by muse, mutect2, varscan2
- INTS6L | c.1306C>T p.R436* | Nonsense Mutation (SNP) | VAF 55/307 reads (18%) | catalogued as COSV66085998; called by muse, mutect2, varscan2
- INTS8 | c.2198G>A p.R733Q | Missense Mutation (SNP) | VAF 73/289 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.477); catalogued as COSV58252911; called by muse, mutect2, varscan2
- IPO11 | c.271C>T p.R91C | Missense Mutation (SNP) | VAF 53/278 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1171733432, COSV57580518; called by muse, mutect2, varscan2
- IPO9 | c.2393C>T p.T798M | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV64233812; called by muse, mutect2
- IRF2 | c.991C>T p.R331W | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs753833490, COSV66930359; called by muse, mutect2, varscan2
- ITPR3 | c.5720C>T p.T1907M | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1277690994, COSV65406512; called by muse, mutect2, varscan2
- JADE2 | c.1394G>A p.R465H | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV50928592; called by muse, mutect2, varscan2
- JARID2 | c.1732C>T p.R578C | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.916); catalogued as rs759192312, COSV59196573; called by muse, mutect2, varscan2
- KANSL1 | c.1775G>A p.R592Q | Missense Mutation (SNP) | VAF 35/114 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52264616; called by muse, mutect2, varscan2
- KANSL1 | c.142G>T p.G48* | Nonsense Mutation (SNP) | VAF 44/162 reads (27%) | catalogued as COSV52273206; called by muse, mutect2, varscan2
- KCNA4 | c.663del p.F221Lfs*21 | Frame Shift Del (DEL) | VAF 7/47 reads (15%) | catalogued as rs754892524; called by mutect2, pindel, varscan2
- KCNH7 | c.1793G>A p.R598H | Missense Mutation (SNP) | VAF 64/279 reads (23%) | SIFT tolerated (0.69); PolyPhen benign (0.003); catalogued as COSV100037771; called by muse, mutect2, varscan2
- KDM2A | c.2198G>A p.R733Q | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT tolerated (0.32); PolyPhen benign (0.441); catalogued as rs772977471, COSV58189564; called by muse, mutect2, varscan2
- KDM3B | c.778G>A p.E260K | Missense Mutation (SNP) | VAF 47/176 reads (27%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.959); catalogued as COSV58694364; called by muse, mutect2, varscan2
- KIAA0100 | c.4720C>T p.R1574* | Nonsense Mutation (SNP) | VAF 61/202 reads (30%) | catalogued as rs148098359; called by muse, mutect2, varscan2
- KIAA1109 | c.10615C>T p.R3539C | Missense Mutation (SNP) | VAF 22/177 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs765987499, COSV52681131; called by muse, mutect2, varscan2
- KIAA1549L | c.4125dup p.T1376Hfs*62 (on ENST00000321505; = p.T1673Hfs*62 on NM_012194.3) | Frame Shift Ins (INS) | VAF 13/83 reads (16%) | catalogued as rs752808243; called by mutect2, pindel, varscan2
- KIAA1755 | c.755A>G p.E252G | Missense Mutation (SNP) | VAF 31/161 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV99642698; called by muse, mutect2, varscan2
- KIF20A | c.399G>T p.Q133H | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1262696257, COSV50165207; called by muse, mutect2, varscan2
- KIF21A | c.578G>A p.R193H | Missense Mutation (SNP) | VAF 62/284 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770064077, COSV62766767; ClinVar: benign; called by muse, mutect2, varscan2
- KIF27 | c.2684C>T p.P895L | Missense Mutation (SNP) | VAF 89/358 reads (25%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs777539862, COSV52829524; called by muse, mutect2, varscan2
- KIR3DX1 | n.75C>T | Splice Region (SNP) | VAF 14/85 reads (16%) | catalogued as rs776938727, COSV55597451; called by mutect2, varscan2
- KIRREL1 | c.1009del p.L337Sfs*14 | Frame Shift Del (DEL) | VAF 35/157 reads (22%) | catalogued as rs754171400, COSV63285253; called by mutect2, pindel, varscan2
- KLHL6 | c.994C>T p.R332W | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.586); catalogued as rs753462867, COSV58068939; called by muse, mutect2, varscan2
- KLK1 | c.776C>T p.A259V | Missense Mutation (SNP) | VAF 19/112 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.021); catalogued as rs767774943, COSV56827308; called by muse, mutect2, varscan2
- KMT2A | c.3799G>A p.V1267I | Missense Mutation (SNP) | VAF 21/104 reads (20%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); catalogued as rs376303494; called by muse, mutect2, varscan2
- KMT2B | c.5572C>T p.R1858C | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs750345473, COSV99720637; called by muse, mutect2, varscan2
- KMT5A | c.322G>A p.A108T | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs376869233; called by muse, mutect2, varscan2
- KRI1 | c.742C>T p.R248C | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.828); catalogued as rs775024147, COSV57263794; called by muse, mutect2, varscan2
- KRT5 | c.1108C>T p.Q370* | Nonsense Mutation (SNP) | VAF 47/162 reads (29%) | catalogued as COSV52863059; called by muse, mutect2, varscan2
- KRT83 | c.908G>A p.R303H | Missense Mutation (SNP) | VAF 39/126 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.024); catalogued as rs775630317, COSV99531914; called by muse, mutect2, varscan2
- LAMC1 | c.3401C>T p.A1134V | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs148780198, COSV51154442; called by muse, mutect2, varscan2
- LAMTOR1 | c.55C>T p.R19W | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0.047); catalogued as rs1470988828, COSV53826789; called by mutect2, varscan2
- LARP4B | c.487del p.T163Hfs*47 | Frame Shift Del (DEL) | VAF 63/270 reads (23%) | catalogued as COSV60222740; called by mutect2, pindel, varscan2
- LARP6 | c.1396G>A p.V466I | Missense Mutation (SNP) | VAF 30/141 reads (21%) | SIFT tolerated (0.3); PolyPhen benign (0.403); catalogued as rs201700915, COSV54582171; called by muse, mutect2, varscan2
- LCN15 | c.306G>A p.P102= | Splice Region (SNP) | VAF 11/46 reads (24%) | catalogued as rs1323060858, COSV60211070; called by muse, mutect2, varscan2
- LGR4 | c.2782C>T p.R928* | Nonsense Mutation (SNP) | VAF 24/83 reads (29%) | catalogued as rs1461413137, COSV58725333; called by muse, mutect2, varscan2
- LLGL2 | c.1994G>A p.R665Q | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.006); catalogued as rs764920758, COSV51415169; called by muse, mutect2, varscan2
- LMNB1 | c.431C>T p.S144L | Missense Mutation (SNP) | VAF 30/140 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.184); catalogued as COSV54396755; called by muse, mutect2, varscan2
- LONP2 | c.1949G>A p.R650H | Missense Mutation (SNP) | VAF 62/374 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs146778858; called by muse, mutect2, varscan2
- LOXL2 | c.1570G>A p.D524N | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0.015); catalogued as rs1302799291, COSV66693309; called by muse, mutect2
- LRG1 | c.271G>A p.A91T | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT tolerated (0.3); PolyPhen benign (0.053); catalogued as rs750105391, COSV56705684; called by muse, mutect2, varscan2
- LRP1 | c.5606G>A p.R1869H | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs564564960, COSV54506145; called by muse, mutect2, varscan2
- LRP2 | c.169G>A p.A57T | Missense Mutation (SNP) | VAF 28/117 reads (24%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as rs147295930, COSV55555420; called by muse, mutect2, varscan2
- LRP4 | c.1048C>T p.R350W | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs368744612, COSV66133835, COSV66138317; called by muse, mutect2, varscan2
- LRPPRC | c.452A>G p.D151G | Missense Mutation (SNP) | VAF 103/462 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.255); catalogued as rs900826601, COSV53242436; called by muse, mutect2, varscan2
- LRRC27 | c.1333G>A p.V445I | Missense Mutation (SNP) | VAF 25/102 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs112108153; called by muse, mutect2
- LRRC37A3 | c.3266C>T p.P1089L | Missense Mutation (SNP) | VAF 56/184 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as rs148306009, COSV58535189; called by muse, mutect2, varscan2
- LRRIQ1 | c.1470dup p.R491Tfs*14 | Frame Shift Ins (INS) | VAF 42/168 reads (25%) | catalogued as rs779699744; called by mutect2, varscan2
- LRRK1 | c.1930G>A p.V644M | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.932); catalogued as rs375903897; called by muse, mutect2, varscan2
- LRRK2 | c.4613G>A p.R1538H | Missense Mutation (SNP) | VAF 28/164 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.912); catalogued as rs200631999, COSV54161630; called by muse, mutect2, varscan2
- LRRK2 | c.5173C>T p.R1725* | Nonsense Mutation (SNP) | VAF 18/102 reads (18%) | catalogued as rs11564176, COSV54163968, COSV54167779; ClinVar: uncertain significance; called by mutect2, varscan2
- LRRTM3 | c.850A>G p.N284D | Missense Mutation (SNP) | VAF 36/146 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV63671002; called by muse, mutect2, varscan2
- LTBP1 | c.2363G>A p.R788Q (on ENST00000404816 / NM_206943.4; = p.R462Q on NM_000627.4) | Missense Mutation (SNP) | VAF 24/99 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs149005748; called by muse, mutect2, varscan2
- LTF | c.1772C>T p.A591V | Missense Mutation (SNP) | VAF 26/116 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs776084962, COSV51607753; called by muse, mutect2, varscan2
- LTV1 | c.20A>G p.K7R | Missense Mutation (SNP) | VAF 29/110 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.42); catalogued as COSV62536719; called by muse, mutect2, varscan2
- LYVE1 | c.143C>T p.A48V | Missense Mutation (SNP) | VAF 38/167 reads (23%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as rs141249676; called by muse, mutect2, varscan2
- LZTS2 | c.1424G>A p.R475Q | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs147628187; called by muse, mutect2, varscan2
- MACO1 | c.306del p.F102Lfs*47 | Frame Shift Del (DEL) | VAF 102/368 reads (28%) | catalogued as rs752439249; called by mutect2, varscan2
- MAGEB16 | c.826C>A p.L276M | Missense Mutation (SNP) | VAF 66/327 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV67874460; called by muse, mutect2, varscan2
- MAMDC4 | c.3182C>A p.P1061H (on ENST00000445819; = p.P982H on NM_206920.3) | Missense Mutation (SNP) | VAF 28/112 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56377186; called by muse, mutect2, varscan2
- MAP2K7 | c.980C>T p.T327M | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.805); catalogued as COSV67608070; called by muse, mutect2, varscan2
- MAP3K9 | c.3007C>T p.R1003W (on ENST00000554752 / NM_001284230.1; = p.R1017W on NM_033141.4) | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs758186971, COSV67122631; called by muse, mutect2, varscan2
- MAP4K4 | c.2230G>A p.A744T (on ENST00000347699 / NM_001242559.2; = p.A662T on NM_004834.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.91); catalogued as rs199996114, COSV56339293; called by muse, mutect2, varscan2
- MBD4 | c.939del p.E314Kfs*4 | Frame Shift Del (DEL) | VAF 44/234 reads (19%) | catalogued as rs558765093; called by mutect2, varscan2
- MC4R | c.974T>C p.L325P | Missense Mutation (SNP) | VAF 26/130 reads (20%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as COSV55353066; called by muse, mutect2, varscan2
- MCTP2 | c.1018C>T p.R340C | Missense Mutation (SNP) | VAF 62/237 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as rs779316690, COSV59149202, COSV59149391; called by muse, mutect2, varscan2
- MDN1 | c.5845C>T p.R1949W | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771685175, COSV65528883; called by muse, mutect2, varscan2
- ME3 | c.962G>A p.R321Q | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as rs770484153, COSV62774683; called by muse, mutect2, varscan2
- MGAT4C | c.1175T>A p.I392N | Missense Mutation (SNP) | VAF 29/128 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV59833204; called by muse, mutect2, varscan2
- MGAT5B | c.1627del p.L543Wfs*71 (on ENST00000569840 / NM_001199172.2; = p.L541Wfs*71 on NM_144677.3) | Frame Shift Del (DEL) | VAF 10/62 reads (16%) | catalogued as rs778939334; called by mutect2, pindel
- MICAL2 | c.1925T>C p.L642P | Missense Mutation (SNP) | VAF 40/206 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV99818366; called by muse, varscan2
- MIDEAS | c.939del p.N314Tfs*4 | Frame Shift Del (DEL) | VAF 6/54 reads (11%) | catalogued as rs762448666; called by mutect2, pindel
- MIGA1 | c.1018C>T p.R340W | Missense Mutation (SNP) | VAF 35/171 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.086); catalogued as rs775316428, COSV66224688; called by muse, mutect2, varscan2
- MINAR1 | c.2734T>C p.C912R | Missense Mutation (SNP) | VAF 16/107 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59585929; called by muse, mutect2, varscan2
- MINDY4 | c.56G>A p.S19N | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as COSV54677861; called by muse, mutect2, varscan2
- MINPP1 | c.1297C>T p.R433* | Nonsense Mutation (SNP) | VAF 54/198 reads (27%) | catalogued as rs1339940985, COSV64355228; called by muse, mutect2, varscan2
- MKI67 | c.7661G>A p.R2554H | Missense Mutation (SNP) | VAF 71/302 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs752347498, COSV100896992; called by muse, mutect2, varscan2
- MKRN3 | c.269G>A p.R90Q | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.027); catalogued as rs140349866; called by muse, mutect2, varscan2
- MMP12 | c.1359C>A p.F453L | Missense Mutation (SNP) | VAF 29/156 reads (19%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV100405077; called by muse, mutect2, varscan2
- MMP13 | c.1373G>A p.R458H | Missense Mutation (SNP) | VAF 27/105 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.08); catalogued as rs1368431302, COSV52825377; called by muse, mutect2, varscan2
- MNAT1 | c.420+2T>C p.X140_splice | Splice Site (SNP) | VAF 54/564 reads (10%) | catalogued as COSV54195308; called by muse, mutect2
- MORN1 | c.1319G>A p.R440H | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs374707849; called by muse, varscan2
- MPIG6B | c.350G>A p.R117H | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.011); catalogued as rs756870049, COSV65389481; called by muse, mutect2, varscan2
- MPL | c.268C>T p.R90* | Nonsense Mutation (SNP) | VAF 26/129 reads (20%) | catalogued as rs763144679, CM010062, COSV65247904; called by muse, mutect2, varscan2
- MPZL2 | c.617A>G p.K206R | Missense Mutation (SNP) | VAF 63/214 reads (29%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.971); catalogued as COSV54049447; called by muse, mutect2, varscan2
- MRE11 | c.1715G>A p.R572Q | Missense Mutation (SNP) | VAF 72/273 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.048); catalogued as rs200085146, COSV60576141; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MRGBP | c.541C>T p.R181W | Missense Mutation (SNP) | VAF 25/144 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.893); catalogued as rs756019296, COSV65111577; called by muse, mutect2, varscan2
- MRPL16 | c.595C>T p.R199* | Nonsense Mutation (SNP) | VAF 27/106 reads (25%) | catalogued as rs779032152, COSV55699803; called by muse, mutect2, varscan2
- MRPS12 | c.266G>A p.R89H | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.686); catalogued as rs768970230, COSV55501401; called by muse, mutect2, varscan2
- MTMR9 | c.880C>T p.R294* | Nonsense Mutation (SNP) | VAF 24/136 reads (18%) | catalogued as rs1192252942, COSV55314924; called by muse, mutect2, varscan2
- MTR | c.3028T>C p.Y1010H | Missense Mutation (SNP) | VAF 38/162 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.012); catalogued as COSV63966139; called by muse, mutect2, varscan2
- MUC16 | c.42064G>A p.G14022S | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.998); catalogued as COSV66695851; called by muse, mutect2, varscan2
- MUC16 | c.26644C>T p.R8882W | Missense Mutation (SNP) | VAF 47/232 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.129); catalogued as rs376649428; called by muse, mutect2, varscan2
- MUC16 | c.25606A>C p.M8536L | Missense Mutation (SNP) | VAF 26/127 reads (20%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); catalogued as COSV67488566; called by muse, mutect2, varscan2
- MUC16 | c.18817A>G p.T6273A | Missense Mutation (SNP) | VAF 32/312 reads (10%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.249); catalogued as COSV67488574; called by muse, mutect2, varscan2
- MUL1 | c.532C>T p.R178W | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs758966256, COSV51641810; called by muse, mutect2, varscan2
- MYH10 | c.2006G>A p.R669Q | Missense Mutation (SNP) | VAF 74/377 reads (20%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.815); catalogued as rs773722498, COSV52602775; called by muse, mutect2, varscan2
- MYH10 | c.1871G>A p.R624H | Missense Mutation (SNP) | VAF 47/193 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.102); catalogued as rs1470703280, COSV52609362; called by muse, mutect2, varscan2
- MYH11 | c.1913C>T p.S638L | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.054); catalogued as rs771128441, COSV55543719; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- MYH13 | c.544G>A p.G182R | Missense Mutation (SNP) | VAF 54/191 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs373315937; called by muse, mutect2, varscan2
- MYH14 | c.5224G>A p.A1742T | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV51829221; called by mutect2, varscan2
- MYH3 | c.4013G>A p.R1338H | Missense Mutation (SNP) | VAF 41/129 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.104); catalogued as rs761937084, COSV99878932; called by muse, mutect2, varscan2
- MYO15A | c.4367G>A p.R1456H | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.09); catalogued as rs1437653270, COSV52764180; called by muse, mutect2, varscan2
- MYO16 | c.3802G>A p.V1268I | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs377315850, COSV100695852; called by muse, varscan2
- MYO16 | c.5072C>T p.A1691V | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.003); catalogued as rs780965692, COSV62747388; called by muse, mutect2, varscan2
- MYO18A | c.4936C>T p.R1646W | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs200860055; called by muse, mutect2, varscan2
- MYO1G | c.944C>T p.T315M | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.232); catalogued as rs774267015, COSV51856660; called by muse, mutect2, varscan2
- MYO5B | c.5269G>A p.A1757T | Missense Mutation (SNP) | VAF 29/117 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs200931302; called by muse, mutect2, varscan2
- MYO7B | c.4132G>A p.A1378T | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated (0.3); PolyPhen benign (0.005); catalogued as rs368090832; called by muse, mutect2, varscan2
- MYO9A | c.6536G>A p.R2179Q | Missense Mutation (SNP) | VAF 68/281 reads (24%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.824); catalogued as rs755715960, COSV61856533; called by muse, mutect2, varscan2
- MYOM3 | c.340G>A p.A114T | Missense Mutation (SNP) | VAF 36/140 reads (26%) | SIFT tolerated (0.36); PolyPhen benign (0.017); catalogued as rs756715948, COSV58399891; called by muse, mutect2, varscan2
- N4BP2 | c.3367A>G p.S1123G | Missense Mutation (SNP) | VAF 79/347 reads (23%) | SIFT tolerated (0.71); PolyPhen benign (0.034); catalogued as COSV54706043; called by muse, mutect2, varscan2
- NAA35 | c.1709G>A p.R570H | Missense Mutation (SNP) | VAF 59/258 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.125); catalogued as COSV64486306; called by muse, mutect2, varscan2
- NALCN | c.5024-2A>C p.X1675_splice | Splice Site (SNP) | VAF 62/252 reads (25%) | catalogued as COSV51960144; called by muse, mutect2
- NAPEPLD | c.1103A>G p.Y368C | Missense Mutation (SNP) | VAF 63/601 reads (10%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.719); catalogued as rs778037217, COSV100085859; called by muse, mutect2, varscan2
- NAV2 | c.2692C>T p.R898W (on ENST00000396087 / NM_001244963.2; = p.R875W on NM_145117.5) | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs374226697; called by mutect2, varscan2
- NAV3 | c.4686T>C p.A1562= | Splice Region (SNP) | VAF 214/928 reads (23%) | catalogued as COSV57107476; called by muse, varscan2
- NAV3 | c.7102G>A p.E2368K (on ENST00000397909 / NM_001024383.2; = p.E2346K on NM_014903.6) | Missense Mutation (SNP) | VAF 62/226 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.012); catalogued as rs756005980, COSV57074126; called by muse, varscan2
- NCAPD3 | c.2848G>A p.E950K | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1437018562, COSV73244918, COSV73244935; called by muse, varscan2
- NDFIP1 | c.302G>A p.R101Q | Missense Mutation (SNP) | VAF 95/491 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs774325360, COSV54076135; called by muse, mutect2, varscan2
- NEB | c.15596T>C p.L5199P | Missense Mutation (SNP) | VAF 47/337 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV51453545; called by muse, mutect2, varscan2
- NEB | c.14455G>A p.E4819K | Missense Mutation (SNP) | VAF 74/356 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.554); catalogued as rs753229810, COSV51453573, COSV51458537; called by muse, mutect2, varscan2
- NEB | c.9694G>A p.A3232T | Missense Mutation (SNP) | VAF 47/167 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV51453605; called by muse, mutect2, varscan2
- NEB | c.4841A>G p.Y1614C | Missense Mutation (SNP) | VAF 92/407 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51453628; called by muse, mutect2, varscan2
- NFASC | c.2494C>T p.R832* (on ENST00000339876 / NM_001378329.1; = p.R935* on NM_015090.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 14/66 reads (21%) | catalogued as rs1420601709, COSV58374054; called by muse, mutect2, varscan2
- NFASC | c.3146C>T p.T1049M | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.833); catalogued as rs370138600; called by muse, mutect2, varscan2
- NGF | c.145C>T p.R49C | Missense Mutation (SNP) | VAF 27/105 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.642); catalogued as rs146716262; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NGFR | c.925G>A p.V309M | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1198547061, COSV50801878; called by muse, mutect2, varscan2
- NISCH | c.2989G>A p.V997I | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs372817454; called by muse, mutect2, varscan2
- NLRP1 | c.226C>T p.Q76* | Nonsense Mutation (SNP) | VAF 12/64 reads (19%) | catalogued as COSV52576442; called by muse, mutect2, varscan2
- NMUR2 | c.848C>T p.P283L | Missense Mutation (SNP) | VAF 59/189 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs369018357, COSV54916843; called by muse, mutect2, varscan2
- NOD2 | c.1515del p.S506Pfs*11 | Frame Shift Del (DEL) | VAF 14/57 reads (25%) | catalogued as rs754761524; ClinVar: uncertain significance; called by mutect2, pindel, varscan2
- NOL4L | c.179C>T p.T60M | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.182); catalogued as rs148352586; called by muse, mutect2, varscan2
- NPTX2 | c.985G>A p.G329R | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs375252857; called by muse, mutect2, varscan2
- NPY2R | c.796dup p.T266Nfs*27 | Frame Shift Ins (INS) | VAF 39/183 reads (21%) | catalogued as rs758758894; called by mutect2, pindel, varscan2
- NRAP | c.617C>T p.T206M | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.677); catalogued as rs752825681, COSV63489506; called by muse, mutect2
- NRP1 | c.271G>A p.D91N | Missense Mutation (SNP) | VAF 50/213 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.297); catalogued as rs533652148, COSV55160529; called by muse, mutect2, varscan2
- NRTN | c.157C>T p.R53C | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.586); catalogued as rs138240507; called by muse, mutect2, varscan2
- NRXN3 | c.1168G>A p.A390T (on ENST00000335750 / NM_001330195.2; = p.A17T on NM_004796.6) | Missense Mutation (SNP) | VAF 34/142 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.942); catalogued as rs541054958, COSV59774535; called by muse, varscan2
- NT5C1B | c.709C>T p.R237C (on ENST00000359846 / NM_001199086.2; = p.R177C on NM_033253.4) | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.91); catalogued as COSV58397243; called by muse, mutect2, varscan2
- NTN5 | c.1009G>T p.G337C | Missense Mutation (SNP) | VAF 22/152 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.43); catalogued as COSV54308565; called by muse, mutect2, varscan2
- NTSR1 | c.496C>T p.R166C | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65137939; called by muse, mutect2, varscan2
- NUDC | c.109C>T p.R37* | Nonsense Mutation (SNP) | VAF 48/183 reads (26%) | catalogued as rs755690181, COSV100345720; called by muse, mutect2, varscan2
- NUMB | c.1351G>A p.V451I (on ENST00000355058; = p.V440I on NM_003744.5) | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.013); catalogued as rs114327279, COSV53719223; called by muse, mutect2, varscan2
- NUP205 | c.5270G>A p.C1757Y | Missense Mutation (SNP) | VAF 66/347 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV53664983; called by muse, mutect2, varscan2
- ONECUT2 | c.1348C>T p.R450C | Missense Mutation (SNP) | VAF 15/147 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs755413489, COSV72153285; called by muse, mutect2, varscan2
- OR13C8 | c.895C>T p.R299* | Nonsense Mutation (SNP) | VAF 53/203 reads (26%) | catalogued as rs201484830, COSV58611653; called by muse, mutect2, varscan2
- OR13G1 | c.676C>T p.R226C | Missense Mutation (SNP) | VAF 24/140 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.336); catalogued as rs138028749; called by muse, mutect2, varscan2
- OR1J1 | c.67C>T p.Q23* | Nonsense Mutation (SNP) | VAF 33/120 reads (28%) | catalogued as rs1305744128, COSV99403265; called by muse, mutect2, varscan2
- OR2T3 | c.315G>T p.Q105H | Missense Mutation (SNP) | VAF 97/437 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62083497; called by muse, mutect2, varscan2
- OR5A1 | c.517G>A p.G173R | Missense Mutation (SNP) | VAF 53/248 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs140829988, COSV100118475; called by muse, mutect2, varscan2
- OR5H14 | c.842T>C p.I281T | Missense Mutation (SNP) | VAF 58/487 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as rs769332187, COSV71194465; called by muse, mutect2, varscan2
- OR9A4 | c.778G>A p.V260M | Missense Mutation (SNP) | VAF 26/97 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.532); catalogued as rs1463927962, COSV71885968; called by muse, mutect2, varscan2
- ORC6 | c.507del p.A170Lfs*10 | Frame Shift Del (DEL) | VAF 33/174 reads (19%) | catalogued as rs35441257; called by mutect2, pindel, varscan2
- OSBPL5 | c.962G>A p.R321Q | Missense Mutation (SNP) | VAF 49/246 reads (20%) | SIFT tolerated (0.57); PolyPhen benign (0.184); catalogued as rs374028974; called by muse, mutect2, varscan2
- OTOP2 | c.1175C>T p.A392V | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.116); catalogued as rs148548570; called by muse, mutect2, varscan2
- OTUD7A | c.914C>T p.P305L (on ENST00000307050 / NM_001382637.1; = p.P298L on NM_130901.3) | Missense Mutation (SNP) | VAF 21/90 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.647); catalogued as COSV61042729; called by muse, mutect2, varscan2
- P2RX3 | c.820G>A p.V274M | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); catalogued as rs369989085; called by muse, mutect2, varscan2
- PAF1 | c.256C>T p.L86F | Missense Mutation (SNP) | VAF 31/141 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55395934; called by muse, varscan2
- PAFAH1B1 | c.1112G>A p.R371Q | Missense Mutation (SNP) | VAF 37/178 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.5); catalogued as rs910626467, COSV68210351; called by muse, mutect2, varscan2
- PAGE2 | c.182C>A p.P61H | Missense Mutation (SNP) | VAF 178/787 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as COSV66596200; called by muse, mutect2, varscan2
- PAK4 | c.1757G>A p.R586H | Missense Mutation (SNP) | VAF 15/104 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.054); catalogued as rs747655225, COSV58946689; called by muse, mutect2, varscan2
- PAM | c.2711C>T p.T904M (on ENST00000438793 / NM_001319943.1; = p.T905M on NM_000919.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 82/319 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.247); catalogued as rs113740014; called by muse, mutect2, varscan2
- PANK4 | c.763C>T p.R255W | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.713); catalogued as rs1404250863, COSV101022565; called by muse, mutect2, varscan2
- PAPLN | c.1342G>A p.V448I (on ENST00000554301; = p.V421I on NM_173462.4) | Missense Mutation (SNP) | VAF 28/154 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.771); catalogued as rs747187995, COSV53722617; called by muse, mutect2, varscan2
- PAPOLG | c.997C>T p.R333* | Nonsense Mutation (SNP) | VAF 53/177 reads (30%) | catalogued as COSV99475118; called by muse, mutect2, varscan2
- PASK | c.2126C>T p.T709M | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.24); catalogued as rs575148483, COSV52148244; called by muse, mutect2, varscan2
- PAXBP1 | c.1487C>T p.S496L | Missense Mutation (SNP) | VAF 44/229 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.241); catalogued as rs1229809110, COSV51611863; called by muse, varscan2
- PCDH15 | c.3709G>A p.D1237N | Missense Mutation (SNP) | VAF 31/139 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.077); catalogued as rs371278220, COSV100217429; called by muse, mutect2, varscan2
- PCDHA2 | c.2116G>A p.A706T | Missense Mutation (SNP) | VAF 43/178 reads (24%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.1); catalogued as COSV65368940; called by muse, mutect2, varscan2
- PCDHB2 | c.1529C>T p.A510V | Missense Mutation (SNP) | VAF 33/146 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.379); catalogued as COSV50620512; called by muse, varscan2
- PCDHGA1 | c.1681G>A p.E561K | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.124); catalogued as rs759644223, COSV65295915, COSV65298942; called by muse, mutect2, varscan2
- PCDHGA7 | c.1438G>A p.D480N | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV54016517; called by muse, mutect2, varscan2
- PCDHGB2 | c.1225G>A p.A409T | Missense Mutation (SNP) | VAF 30/114 reads (26%) | SIFT tolerated (0.86); PolyPhen benign (0.017); catalogued as rs772255956, COSV54016495; called by muse, mutect2, varscan2
- PCF11 | c.4579C>T p.R1527* | Nonsense Mutation (SNP) | VAF 30/118 reads (25%) | catalogued as COSV53536961; called by muse, mutect2, varscan2
- PCLO | c.7325del p.K2442Sfs*2 | Frame Shift Del (DEL) | VAF 8/58 reads (14%) | catalogued as COSV61618667; called by mutect2, varscan2
- PCSK5 | c.3916G>A p.G1306R | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.498); catalogued as rs781133062, COSV101377705; called by mutect2, varscan2
- PDSS1 | c.802G>A p.A268T | Missense Mutation (SNP) | VAF 69/269 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767397399, COSV100873470; called by muse, mutect2, varscan2
- PEG10 | c.383G>A p.R128H (on ENST00000482108 / NM_001040152.2; = p.R162H on NM_015068.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.995); catalogued as COSV71788627; called by muse, mutect2, varscan2
- PELI3 | c.910C>T p.R304C | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778577702, COSV57857593; called by muse, mutect2, varscan2
- PER3 | c.1310G>A p.S437N | Missense Mutation (SNP) | VAF 33/129 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV100728482; called by muse, mutect2, varscan2
- PGD | c.1117C>A p.L373I | Missense Mutation (SNP) | VAF 34/142 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV54622991; called by muse, mutect2, varscan2
- PHC3 | c.2516G>A p.R839H (on ENST00000494943 / NM_001308116.2; = p.R851H on NM_024947.4) | Missense Mutation (SNP) | VAF 42/225 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as rs778400657, COSV71949266; called by muse, mutect2, varscan2
- PHF13 | c.731G>A p.R244H | Missense Mutation (SNP) | VAF 43/162 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs754829891, COSV50011078; called by muse, varscan2
- PHF14 | c.1427G>C p.G476A | Missense Mutation (SNP) | VAF 42/212 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV68856991; called by muse, mutect2, varscan2
- PHYHIP | c.614G>A p.R205H | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58689274; called by muse, mutect2, varscan2
- PIGR | c.184G>A p.G62S | Missense Mutation (SNP) | VAF 35/155 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.617); catalogued as COSV62904859; called by muse, varscan2
- PIGZ | c.1467del p.T490Lfs*10 | Frame Shift Del (DEL) | VAF 5/29 reads (17%) | catalogued as rs759867499; called by pindel, varscan2
- PIKFYVE | c.4066G>A p.A1356T | Missense Mutation (SNP) | VAF 49/167 reads (29%) | SIFT tolerated (0.45); PolyPhen benign (0.137); catalogued as COSV52248001; called by muse, mutect2, varscan2
- PKD1L2 | n.430del | Splice Region (DEL) | VAF 13/77 reads (17%) | catalogued as rs755082958; called by mutect2, pindel, varscan2
- PKDREJ | c.3517C>T p.R1173W | Missense Mutation (SNP) | VAF 28/85 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.874); catalogued as rs546765847, COSV53550947, COSV53552415; called by muse, mutect2, varscan2
- PLCE1 | c.4577C>A p.P1526H | Missense Mutation (SNP) | VAF 73/329 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53368145; called by muse, mutect2, varscan2
- PLEC | c.12821G>A p.R4274H (on ENST00000322810 / NM_201380.4; = p.R4164H on NM_000445.5) | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs781988786, COSV59686457; called by muse, mutect2, varscan2
- PLEC | c.10837G>A p.D3613N (on ENST00000322810 / NM_201380.4; = p.D3503N on NM_000445.5) | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs782148173, COSV59686511; called by muse, mutect2
- PLEC | c.7549G>A p.A2517T (on ENST00000322810 / NM_201380.4; = p.A2407T on NM_000445.5) | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.031); catalogued as rs531930290, COSV100519009; called by muse, mutect2, varscan2
- PLSCR3 | c.278G>A p.R93Q | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.297); catalogued as rs1384127781, COSV100247922, COSV61172263; called by mutect2, varscan2
- PLXNB1 | c.536del p.G179Vfs*41 | Frame Shift Del (DEL) | VAF 8/42 reads (19%) | catalogued as rs953293505; called by mutect2, pindel, varscan2
- PLXNB2 | c.3394G>A p.V1132M | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV63783992; called by mutect2, varscan2
- PNMA8A | c.848C>T p.A283V | Missense Mutation (SNP) | VAF 17/110 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.034); catalogued as rs761401941, COSV100562431; called by muse, mutect2, varscan2
- PNPLA3 | c.686del p.P229Rfs*34 | Frame Shift Del (DEL) | VAF 11/73 reads (15%) | catalogued as COSV53381029; called by mutect2, pindel
- POLD1 | c.2048G>A p.R683H | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs754913337, COSV70956963; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- POLE | c.6496G>A p.D2166N | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs759795841, COSV57688780, COSV57693292; called by mutect2, varscan2
- POLQ | c.6008C>T p.P2003L | Missense Mutation (SNP) | VAF 43/171 reads (25%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.965); catalogued as rs773624174, COSV51747978; called by muse, mutect2, varscan2
- POLR1A | c.215G>A p.S72N | Missense Mutation (SNP) | VAF 28/135 reads (21%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV55698638; called by muse, mutect2, varscan2
- POLR2F | c.193G>A p.V65M | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs760223334, COSV68091977; called by muse, mutect2, varscan2
- POLR3K | c.314G>A p.R105H | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.038); catalogued as rs182344447; called by muse, mutect2, varscan2
- POMT1 | c.1420G>A p.A474T | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.743); catalogued as rs150702948; ClinVar: uncertain significance; called by mutect2, varscan2
- PON1 | c.79C>T p.R27* | Nonsense Mutation (SNP) | VAF 27/112 reads (24%) | catalogued as rs565598241, COSV55932239; called by muse, mutect2, varscan2
- PPARGC1A | c.2131C>T p.R711W | Missense Mutation (SNP) | VAF 34/185 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.623); catalogued as rs753923087, COSV53530470, COSV53532733; called by muse, mutect2, varscan2
- PPP1R12B | c.2410C>T p.R804* | Nonsense Mutation (SNP) | VAF 22/85 reads (26%) | catalogued as rs1293881866, COSV51789088; called by muse, mutect2, varscan2
- PPP1R13B | c.2624C>T p.S875L | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1252412178, COSV52455650; called by muse, mutect2, varscan2
- PPP2R3C | c.67del p.S23Vfs*5 | Frame Shift Del (DEL) | VAF 52/220 reads (24%) | catalogued as rs758484975; called by mutect2, varscan2
- PREPL | c.1145G>A p.R382Q | Missense Mutation (SNP) | VAF 24/91 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.045); catalogued as rs1325868381, COSV53218986; called by muse, mutect2, varscan2
- PRG4 | c.235G>A p.E79K | Missense Mutation (SNP) | VAF 42/164 reads (26%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.689); catalogued as rs1479398866, COSV66624316; called by muse, mutect2, varscan2
- PRICKLE3 | c.1418G>A p.R473H | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.038); catalogued as rs1557099937, COSV100889951; called by muse, mutect2, varscan2
- PRKAA1 | c.1156C>T p.R386C | Missense Mutation (SNP) | VAF 70/306 reads (23%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.891); catalogued as rs866107019, COSV57186113; called by muse, mutect2, varscan2
- PRKCD | c.385C>T p.Q129* | Nonsense Mutation (SNP) | VAF 18/71 reads (25%) | catalogued as COSV57850985; called by muse, mutect2, varscan2
- PRKDC | c.496del p.I166Yfs*6 | Frame Shift Del (DEL) | VAF 52/339 reads (15%) | catalogued as rs537061158; called by mutect2, varscan2
- PRORP | c.668C>T p.S223L | Missense Mutation (SNP) | VAF 39/162 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.444); catalogued as COSV51622529; called by muse, mutect2, varscan2
- PRR11 | c.66del p.E23Kfs*9 | Frame Shift Del (DEL) | VAF 78/267 reads (29%) | catalogued as rs753236928; called by mutect2, varscan2
- PRRG1 | c.401del p.P134Hfs*19 | Frame Shift Del (DEL) | VAF 33/146 reads (23%) | catalogued as rs781858060; called by mutect2, varscan2
- PRSS35 | c.1058G>A p.R353H | Missense Mutation (SNP) | VAF 30/115 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs757842601, COSV63800328; called by muse, mutect2, varscan2
- PSG8 | c.397G>T p.G133* | Nonsense Mutation (SNP) | VAF 61/358 reads (17%) | catalogued as COSV60614978; called by muse, mutect2, varscan2
- PSMB5 | c.630G>T p.Q210H | Missense Mutation (SNP) | VAF 30/185 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.219); catalogued as COSV100557420; called by muse, mutect2, varscan2
- PSMD11 | c.463C>T p.R155W | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.649); catalogued as rs200794922, COSV55580803; called by muse, mutect2, varscan2
- PSMD5 | c.1490C>T p.T497M | Missense Mutation (SNP) | VAF 76/304 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.873); catalogued as rs752722111, COSV99270670; called by muse, mutect2, varscan2
- PTPN3 | c.1138C>T p.R380* | Nonsense Mutation (SNP) | VAF 42/155 reads (27%) | catalogued as rs185821807, COSV52702416; called by muse, mutect2, varscan2
- PTPRR | c.1321G>A p.D441N | Missense Mutation (SNP) | VAF 65/365 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs192322137, COSV51727223; called by muse, mutect2, varscan2
- PTPRU | c.2009C>T p.A670V | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.049); catalogued as rs147046605; called by muse, mutect2, varscan2
- PUM2 | c.3089G>A p.R1030H | Missense Mutation (SNP) | VAF 79/304 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs770281539, COSV57584637; called by muse, mutect2, varscan2
- PXDNL | c.2569G>A p.A857T | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.066); catalogued as COSV62496833; called by muse, mutect2, varscan2
- QARS1 | c.2080C>T p.R694* | Nonsense Mutation (SNP) | VAF 14/96 reads (15%) | catalogued as rs746293241, COSV60276005; called by muse, mutect2, varscan2
- QSOX2 | c.1891G>A p.G631R | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT tolerated (0.52); PolyPhen benign (0.038); catalogued as rs771629774, COSV62395093; called by muse, mutect2, varscan2
- QTRT1 | c.629G>A p.R210Q | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs997795219, COSV51552425; called by muse, mutect2
- RAB12 | c.482C>T p.T161M | Missense Mutation (SNP) | VAF 25/92 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as rs184470375; called by muse, mutect2, varscan2
- RABGAP1 | c.2789dup p.N930Kfs*7 | Frame Shift Ins (INS) | VAF 30/126 reads (24%) | catalogued as rs749213218; called by mutect2, varscan2
- RABGGTA | c.1009C>T p.R337C | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs762590027, COSV53771562; called by muse, mutect2, varscan2
- RAC2 | c.197G>A p.R66H | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.976); catalogued as COSV50774091; called by mutect2, varscan2
- RAC3 | c.571G>A p.V191I | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0); catalogued as rs1229366485, COSV60712752; called by muse, mutect2, varscan2
- RAD18 | c.1126A>G p.K376E | Missense Mutation (SNP) | VAF 139/751 reads (19%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV53752407; called by muse, mutect2, varscan2
- RAD23A | c.856G>A p.E286K | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.79); catalogued as COSV57538675; called by muse, mutect2, varscan2
- RAD54L2 | c.464C>T p.P155L | Missense Mutation (SNP) | VAF 26/136 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as rs200398242, COSV56581065; called by muse, mutect2, varscan2
- RAF1 | c.118C>T p.R40C | Missense Mutation (SNP) | VAF 78/314 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.794); catalogued as rs772390935, COSV52583127; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RAI1 | c.3182C>T p.T1061M | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as rs770943182, COSV55398030; called by mutect2, varscan2
- RANBP3 | c.1688C>T p.T563M (on ENST00000340578 / NM_007322.3; = p.T558M on NM_003624.3) | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.451); catalogued as rs1019431734, COSV50380327; called by mutect2, varscan2
- RANBP6 | c.1394G>A p.R465H | Missense Mutation (SNP) | VAF 28/121 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs761267698, COSV52391209, COSV52391939; called by muse, mutect2, varscan2
- RAPH1 | c.952G>A p.V318I (on ENST00000319170 / NM_213589.3; = p.V370I on NM_203365.4) | Missense Mutation (SNP) | VAF 52/189 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1170890902, COSV57356905; called by muse, mutect2, varscan2
- RBM15 | c.1157C>T p.T386M | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV63924318; called by muse, mutect2, varscan2
- RBM19 | c.1576G>A p.D526N | Missense Mutation (SNP) | VAF 19/102 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.581); catalogued as rs200306327; called by muse, mutect2, varscan2
- RBM25 | c.1250G>A p.R417Q | Missense Mutation (SNP) | VAF 25/128 reads (20%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.602); catalogued as rs1364276493, COSV56202337; called by muse, varscan2
- RBM43 | c.406del p.I136Sfs*4 | Frame Shift Del (DEL) | VAF 38/152 reads (25%) | catalogued as rs142934811, CD1212851; called by mutect2, varscan2
- RCBTB2 | c.298dup p.I100Nfs*27 | Frame Shift Ins (INS) | VAF 36/192 reads (19%) | catalogued as rs767856805; called by mutect2, varscan2
- RCC2 | c.898C>T p.R300W | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64905460; called by muse, mutect2, varscan2
- REG1A | c.397A>G p.N133D | Missense Mutation (SNP) | VAF 36/132 reads (27%) | SIFT tolerated (0.25); PolyPhen benign (0.223); catalogued as COSV52071223; called by muse, mutect2, varscan2
- REP15 | c.210G>T p.K70N | Missense Mutation (SNP) | VAF 25/115 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.009); catalogued as rs1163937328, COSV57297722; called by muse, mutect2, varscan2
- REST | c.1732del p.S578Vfs*7 | Frame Shift Del (DEL) | VAF 53/236 reads (22%) | catalogued as rs1199978831; called by mutect2, pindel, varscan2
- RGS1 | c.121dup p.R41Kfs*38 | Frame Shift Ins (INS) | VAF 27/164 reads (16%) | catalogued as rs1413536387; called by mutect2, pindel, varscan2
- RGS12 | c.2686G>A p.A896T | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT tolerated (0.36); PolyPhen benign (0.014); catalogued as rs758297073, COSV58756105; called by muse, mutect2, varscan2
- RHOXF1 | c.323C>T p.T108M | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0.228); catalogued as rs1385779747, COSV54295606; called by muse, mutect2
- RNF123 | c.3626G>A p.R1209H | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs754168663, COSV57539369; called by muse, mutect2, varscan2
- RNF20 | c.487G>A p.A163T | Missense Mutation (SNP) | VAF 30/109 reads (28%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.977); catalogued as COSV66355619; called by muse, mutect2, varscan2
- RP1 | c.458del p.P153Hfs*4 | Frame Shift Del (DEL) | VAF 11/43 reads (26%) | catalogued as rs781249059; called by mutect2, pindel
- RP1 | c.6161T>C p.L2054P | Missense Mutation (SNP) | VAF 63/274 reads (23%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV55124843; called by muse, mutect2, varscan2
- RPE65 | c.1451-2A>G p.X484_splice | Splice Site (SNP) | VAF 14/80 reads (18%) | catalogued as COSV99254304; called by muse, mutect2
- RPL32 | c.7G>A p.A3T | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.01); catalogued as rs1358366517, COSV56233500; called by muse, mutect2, varscan2
- RPS6KA1 | c.118G>A p.V40I | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as rs778579909, COSV64810406; called by muse, mutect2, varscan2
- RPS7 | c.347G>A p.R116H | Missense Mutation (SNP) | VAF 43/217 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.114); catalogued as COSV100514012; called by muse, mutect2, varscan2
- RREB1 | c.2883G>T p.E961D | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs1225128181, COSV58563923; called by muse, mutect2, varscan2
- RRP12 | c.3844C>T p.R1282* | Nonsense Mutation (SNP) | VAF 26/85 reads (31%) | catalogued as COSV59670980; called by muse, mutect2, varscan2
- S100A16 | c.271G>A p.A91T | Missense Mutation (SNP) | VAF 25/122 reads (20%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.934); catalogued as rs201595733, COSV100905884, COSV100905904; called by muse, mutect2, varscan2
- S1PR1 | c.772G>A p.V258I | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV59514381; called by muse, mutect2, varscan2
- S1PR4 | c.739C>T p.R247C | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.471); catalogued as rs200375168, COSV99859557; called by muse, mutect2, varscan2
- SAFB2 | c.2471del p.G824Afs*8 | Frame Shift Del (DEL) | VAF 11/50 reads (22%) | catalogued as rs759920279; called by pindel, varscan2
- SAMD4A | c.1745C>T p.P582L | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.535); catalogued as rs758565377, COSV51886987; called by muse, mutect2, varscan2
- SBK2 | c.224G>A p.R75H | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT tolerated (0.26); PolyPhen benign (0.218); catalogued as rs779600909, COSV60015719; called by muse, mutect2, varscan2
- SCAPER | c.1976G>A p.R659H | Missense Mutation (SNP) | VAF 57/615 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs954630744, COSV57740647; called by muse, mutect2
- SDK1 | c.5102C>T p.P1701L | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs371544471; called by muse, mutect2, varscan2
- SEC31A | c.1384del p.I462Lfs*16 | Frame Shift Del (DEL) | VAF 136/409 reads (33%) | catalogued as rs748463349, COSV52348607; called by mutect2, varscan2
- SEMA6A | c.2315G>A p.R772H | Missense Mutation (SNP) | VAF 28/109 reads (26%) | SIFT tolerated (0.55); PolyPhen probably damaging (0.999); catalogued as rs764283270, COSV99145961; called by muse, mutect2, varscan2
- SETX | c.1744C>T p.H582Y | Missense Mutation (SNP) | VAF 38/181 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.335); catalogued as rs1189732521, COSV56393140; called by muse, mutect2, varscan2
- SFTPC | c.201+1G>A p.X67_splice | Splice Site (SNP) | VAF 27/97 reads (28%) | catalogued as COSV59346101; called by muse, mutect2, varscan2
- SH2D4A | c.709C>T p.R237* | Nonsense Mutation (SNP) | VAF 10/33 reads (30%) | catalogued as rs778192807, COSV56121391; called by muse, mutect2, varscan2
- SH3BP5L | c.910G>A p.G304R | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV63539807; called by muse, varscan2
- SHC1 | c.1742G>A p.R581Q (on ENST00000368445 / NM_183001.5; = p.R472Q on NM_003029.5) | Missense Mutation (SNP) | VAF 29/116 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.242); catalogued as rs780518716, COSV63535121; called by muse, mutect2, varscan2
- SIN3A | c.3419G>A p.R1140Q | Missense Mutation (SNP) | VAF 61/244 reads (25%) | SIFT tolerated (0.83); PolyPhen benign (0.003); catalogued as rs754243706, COSV64584642; called by muse, mutect2, varscan2
- SIPA1L1 | c.2498C>T p.P833L | Missense Mutation (SNP) | VAF 12/101 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); catalogued as rs767251862, COSV62168928; called by muse, mutect2, varscan2
- SIRT2 | c.586G>A p.V196I | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT tolerated (0.52); PolyPhen benign (0.001); catalogued as rs200616294; called by muse, mutect2, varscan2
- SLAIN1 | c.1226G>A p.R409Q (on ENST00000466548; = p.R146Q on NM_144595.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/122 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1356534739, COSV57388792, COSV99935440; called by muse, varscan2
- SLC13A2 | c.1299G>T p.K433N | Missense Mutation (SNP) | VAF 26/120 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.366); catalogued as COSV58998127; called by muse, mutect2, varscan2
- SLC1A5 | c.1144G>A p.G382S | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs764434057, COSV69467378; called by muse, varscan2
- SLC22A10 | c.568G>A p.A190T | Missense Mutation (SNP) | VAF 58/251 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.123); catalogued as rs755449796, COSV60423257; called by muse, mutect2, varscan2
- SLC22A12 | c.1284C>T p.H428= | Splice Region (SNP) | VAF 7/38 reads (18%) | catalogued as rs767327882, COSV100327526; called by muse, mutect2, varscan2
- SLC24A5 | c.1210G>A p.V404M | Missense Mutation (SNP) | VAF 67/275 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as rs1009559479, COSV51052121; called by muse, mutect2, varscan2
- SLC25A32 | c.83C>T p.A28V | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV52569146, COSV99884352; called by muse, mutect2, varscan2
- SLC25A42 | c.533C>T p.S178L | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT tolerated (0.65); PolyPhen benign (0.018); catalogued as rs1323880492, COSV59379428; called by mutect2, varscan2
- SLC27A2 | c.832G>A p.G278R | Missense Mutation (SNP) | VAF 69/327 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs147761579, COSV51063876; called by muse, mutect2, varscan2
- SLC29A1 | c.520G>C p.A174P | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV57577895, COSV57580192; called by muse, mutect2, varscan2
- SLC35F4 | c.979G>A p.A327T (on ENST00000339762 / NM_001352015.2; = p.A291T on NM_001206920.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.009); catalogued as rs768850457, COSV60266776; called by muse, mutect2, varscan2
- SLC35F5 | c.251T>C p.V84A | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.956); catalogued as COSV55520310; called by muse, mutect2, varscan2
- SLC37A1 | c.734C>T p.P245L | Missense Mutation (SNP) | VAF 80/277 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs1005655709, COSV61402533, COSV61403500; called by muse, mutect2, varscan2
- SLC39A3 | c.370G>A p.G124R | Missense Mutation (SNP) | VAF 24/101 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); catalogued as rs775552929, COSV54118817; called by muse, mutect2, varscan2
- SLC45A1 | c.626C>T p.S209L | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs747114469, COSV99239634; called by mutect2, varscan2
- SLC49A3 | c.1243del p.E415Rfs*12 (on ENST00000404286 / NM_001294341.2; = p.E414Rfs*12 on NM_032219.4) | Frame Shift Del (DEL) | VAF 10/46 reads (22%) | catalogued as rs762857248; called by mutect2, pindel, varscan2
- SLC4A10 | c.1690A>C p.T564P (on ENST00000446997 / NM_001354461.2; = p.T534P on NM_022058.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 78/426 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV55796439; called by muse, mutect2, varscan2
- SLC4A11 | c.470G>A p.R157H | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs146233650; called by muse, mutect2, varscan2
- SLC66A1 | c.206C>T p.A69V | Missense Mutation (SNP) | VAF 40/129 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as rs755077935, COSV64321321; called by muse, mutect2, varscan2
- SLC8A2 | c.2099C>T p.T700M | Missense Mutation (SNP) | VAF 49/189 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs1429182802, COSV52642427; called by muse, mutect2, varscan2
- SLC8B1 | c.191G>A p.R64H | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.88); catalogued as rs763544176, COSV52527510, COSV99176857; called by muse, mutect2, varscan2
- SLC9A1 | c.475G>A p.D159N | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.28); PolyPhen benign (0.015); catalogued as rs538855887, COSV56056275; called by muse, mutect2, varscan2
- SLCO4A1 | c.1777C>A p.L593I | Missense Mutation (SNP) | VAF 58/248 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.039); catalogued as COSV53893390; called by muse, varscan2
- SMARCB1 | c.991C>T p.R331C (on ENST00000263121; = p.R377C on NM_003073.5) | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as COSV51954280; called by muse, mutect2, varscan2
- SMARCD3 | c.1334G>A p.R445H (on ENST00000262188 / NM_001003801.2; = p.R432H on NM_003078.4) | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs903282679, COSV99223336; called by muse, mutect2, varscan2
- SND1 | c.1906C>T p.R636C | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100691099; called by mutect2, varscan2
- SNRPN | c.514C>T p.R172W | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV100578297, COSV57599968; called by muse, varscan2
- SNTG2 | c.1208T>C p.V403A | Missense Mutation (SNP) | VAF 22/112 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV100424834; called by muse, mutect2
- SNX11 | c.295C>T p.R99* | Nonsense Mutation (SNP) | VAF 20/87 reads (23%) | catalogued as rs751061507, COSV63659165; called by muse, mutect2, varscan2
- SNX15 | c.214C>T p.R72C | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs747933570, COSV57248365; called by muse, mutect2, varscan2
- SNX18 | c.1117G>A p.D373N | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.975); catalogued as rs772299231, COSV57991753; called by muse, mutect2, varscan2
- SNX30 | c.461C>A p.P154H | Missense Mutation (SNP) | VAF 122/491 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65294012; called by muse, mutect2, varscan2
- SOGA1 | c.3238C>T p.R1080C | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.59); catalogued as rs370485293; called by muse, mutect2, varscan2
- SOGA1 | c.1807C>T p.R603C | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1313458212, COSV52928874; called by muse, mutect2, varscan2
- SOX6 | c.1841G>A p.R614H (on ENST00000528429 / NM_001145819.2; = p.R587H on NM_017508.3) | Missense Mutation (SNP) | VAF 61/174 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.713); catalogued as rs1242397325, COSV100321255, COSV57053359; called by muse, mutect2, varscan2
- SPACA3 | c.635G>A p.G212D | Missense Mutation (SNP) | VAF 26/158 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.967); catalogued as COSV52192424; called by muse, mutect2, varscan2
- SPAG11A | c.169G>A p.A57T | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs1262917672; called by mutect2, varscan2
- SPART | c.1513G>A p.V505I | Missense Mutation (SNP) | VAF 62/322 reads (19%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs778801809, COSV62085567; ClinVar: likely benign; called by muse, mutect2, varscan2
- SPATA13 | c.1840C>T p.R614C | Missense Mutation (SNP) | VAF 23/105 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as rs758752942, COSV57981023; called by muse, mutect2, varscan2
- SPATA20 | c.1908C>T p.D636= (on ENST00000356488 / NM_001258372.1; = p.D652= on NM_022827.4) | Splice Region (SNP) | VAF 15/71 reads (21%) | catalogued as rs368963636, COSV50066666; called by muse, mutect2, varscan2
- SPATC1 | c.1294G>A p.E432K | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.123); catalogued as rs377485741; called by muse, mutect2, varscan2
- SPEN | c.10703C>T p.T3568M | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.127); catalogued as rs1023242507, COSV100999065; called by muse, mutect2
- SPRED2 | c.628G>A p.D210N | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.704); catalogued as rs1171746264, COSV62692274; called by mutect2, varscan2
- SPTBN1 | c.6418C>T p.R2140W | Missense Mutation (SNP) | VAF 57/222 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.517); catalogued as rs1558480230, COSV61693071; called by muse, mutect2, varscan2
- SREK1IP1 | c.381del p.K129Nfs*29 | Frame Shift Del (DEL) | VAF 66/343 reads (19%) | catalogued as rs1470980144, COSV72486131; called by mutect2, varscan2
- SREK1IP1 | c.271del p.R91Gfs*67 | Frame Shift Del (DEL) | VAF 151/898 reads (17%) | catalogued as rs750306056; called by mutect2, varscan2
- SRP72 | c.25del p.V9Cfs*10 | Frame Shift Del (DEL) | VAF 4/24 reads (17%) | catalogued as rs763130641; called by mutect2, pindel
- SRR | c.119G>A p.R40H | Missense Mutation (SNP) | VAF 44/184 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as rs766468296, COSV60737804; called by muse, mutect2, varscan2
- SRRM1 | c.1736G>A p.R579Q | Missense Mutation (SNP) | VAF 29/145 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.953); catalogued as rs199920108, COSV100105160; called by muse, mutect2, varscan2
- SSH3 | c.653G>A p.G218D | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.082); catalogued as rs1276678678, COSV57385303, COSV57386429; called by muse, mutect2, varscan2
- SSH3 | c.992G>A p.R331H | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.125); catalogued as rs780187148, COSV57383764; called by muse, mutect2, varscan2
- SSX2IP | c.1515G>T p.W505C | Missense Mutation (SNP) | VAF 29/95 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.01); catalogued as COSV60554320; called by muse, mutect2, varscan2
- STAM2 | c.371C>A p.P124H | Missense Mutation (SNP) | VAF 35/184 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55733757; called by muse, mutect2, varscan2
- STAMBPL1 | c.1214del p.K405Rfs*21 | Frame Shift Del (DEL) | VAF 15/74 reads (20%) | catalogued as rs752994755; called by mutect2, varscan2
- STOML3 | c.272T>C p.V91A | Missense Mutation (SNP) | VAF 14/116 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs1331949830, COSV65511605; called by muse, mutect2, varscan2
- SUCLA2 | c.1210C>T p.R404C (on ENST00000643023; = p.R383C on NM_003850.3) | Missense Mutation (SNP) | VAF 47/250 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as rs781744671, COSV66222887; called by muse, mutect2, varscan2
- SVIL | c.5586del p.M1863Wfs*44 (on ENST00000355867 / NM_021738.3; = p.M1437Wfs*44 on NM_003174.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 25/133 reads (19%) | catalogued as rs770033147; called by mutect2, pindel, varscan2
- SYAP1 | c.454C>T p.R152C | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs140529370, COSV66468024; called by muse, mutect2, varscan2
- SYCP2 | c.3071del p.N1024Tfs*26 | Frame Shift Del (DEL) | VAF 70/295 reads (24%) | catalogued as rs753462162; called by mutect2, varscan2
- SYN3 | c.629A>G p.Q210R | Missense Mutation (SNP) | VAF 18/194 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56666380; called by muse, mutect2
- SYNE1 | c.24016G>A p.D8006N (on ENST00000367255 / NM_182961.4; = p.D7935N on NM_033071.3) | Missense Mutation (SNP) | VAF 42/234 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55079449; called by muse, mutect2, varscan2
- SYNE1 | c.17213T>C p.V5738A (on ENST00000367255 / NM_182961.4; = p.V5667A on NM_033071.3) | Missense Mutation (SNP) | VAF 87/390 reads (22%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.995); catalogued as COSV55079482; called by muse, mutect2, varscan2
- SYNE1 | c.16264C>T p.Q5422* (on ENST00000367255 / NM_182961.4; = p.Q5351* on NM_033071.3) | Nonsense Mutation (SNP) | VAF 47/248 reads (19%) | catalogued as COSV99578715; called by muse, mutect2, varscan2
- SYNE1 | c.15259C>T p.R5087W (on ENST00000367255 / NM_182961.4; = p.R5016W on NM_033071.3) | Missense Mutation (SNP) | VAF 46/179 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.124); catalogued as rs767636254, COSV54909831; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SYNE2 | c.3664C>T p.R1222W | Missense Mutation (SNP) | VAF 44/241 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.17); catalogued as rs773994020, COSV100648495; ClinVar: likely benign; called by muse, varscan2
- SYNE3 | c.817G>A p.E273K | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.043); catalogued as rs749983870, COSV62082068; called by muse, mutect2, varscan2
- SYNPO2 | c.1060C>T p.R354W | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs752586063, COSV61106178; called by mutect2, varscan2
- SYNPO2 | c.1328C>T p.S443L | Missense Mutation (SNP) | VAF 30/178 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV61115786; called by muse, mutect2, varscan2
- SYT9 | c.1204C>T p.R402* | Nonsense Mutation (SNP) | VAF 24/109 reads (22%) | catalogued as rs543709489, COSV59623964; called by muse, mutect2, varscan2
- TACR2 | c.425G>A p.R142Q | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs199608050, COSV64822691; called by muse, mutect2, varscan2
- TAF11 | c.487G>A p.G163R | Missense Mutation (SNP) | VAF 40/138 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs754844977, COSV104387163, COSV51959562; called by muse, mutect2, varscan2
- TAF1D | c.635+1G>A p.X212_splice | Splice Site (SNP) | VAF 72/337 reads (21%) | catalogued as rs1277509261, COSV58681471; called by muse, mutect2, varscan2
- TBCD | c.1473G>A p.S491= | Splice Region (SNP) | VAF 16/57 reads (28%) | catalogued as rs527893726, COSV62803564; called by muse, mutect2, varscan2
- TBX6 | c.1057C>A p.P353T | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs1427212221, COSV54222008; called by mutect2, varscan2
- TCEA2 | c.563G>A p.R188H | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs1411134921, COSV58659195; called by muse, mutect2, varscan2
- TCEAL5 | c.371C>T p.T124M | Missense Mutation (SNP) | VAF 166/707 reads (23%) | SIFT tolerated (0.11); PolyPhen probably damaging (1); catalogued as COSV65503429; called by muse, mutect2, varscan2
- TEAD2 | c.883del p.H295Mfs*12 | Frame Shift Del (DEL) | VAF 12/64 reads (19%) | catalogued as rs763321097; called by mutect2, varscan2
- TECR | c.422G>A p.R141H | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as COSV53109023; called by muse, mutect2, varscan2
- TENM3 | c.2035G>A p.E679K | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.066); catalogued as COSV69313427; called by muse, mutect2, varscan2
- TEX15 | c.1639A>G p.N547D (on ENST00000256246; = p.N930D on NM_001350162.2) | Missense Mutation (SNP) | VAF 74/301 reads (25%) | SIFT tolerated (0.67); PolyPhen benign (0.047); catalogued as COSV56352409; called by muse, mutect2, varscan2
- TFRC | c.1937G>A p.R646H | Missense Mutation (SNP) | VAF 34/166 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV64056160; called by muse, mutect2, varscan2
- TGM2 | c.949C>T p.R317C | Missense Mutation (SNP) | VAF 29/150 reads (19%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.99); catalogued as rs781011976, COSV63931355; called by muse, mutect2, varscan2
- THAP4 | c.772C>T p.R258C | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs1395866062, COSV67192594; called by muse, mutect2, varscan2
- TICAM1 | c.785C>T p.A262V | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.006); catalogued as rs1260265211, COSV50239080; called by muse, mutect2, varscan2
- TIE1 | c.2878G>A p.A960T | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755542003, COSV65250755; called by muse, mutect2, varscan2
- TIMM17B | c.316C>T p.R106C | Missense Mutation (SNP) | VAF 40/131 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.871); catalogued as rs1181980897, COSV54431634; called by muse, mutect2, varscan2
- TIMM22 | c.274G>A p.A92T | Missense Mutation (SNP) | VAF 152/600 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs142652142; called by muse, mutect2, varscan2
- TIMM50 | c.973C>T p.R325C | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs746734633, COSV58680523; called by muse, mutect2, varscan2
- TMC3 | c.2900G>A p.R967H | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1423516565, COSV63924406; called by muse, mutect2, varscan2
- TMCO4 | c.378G>T p.K126N | Missense Mutation (SNP) | VAF 51/204 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.149); catalogued as COSV53876496; called by muse, mutect2, varscan2
- TMEM120B | c.796C>T p.R266W | Missense Mutation (SNP) | VAF 43/181 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs375346644; called by muse, mutect2, varscan2
- TMEM121 | c.121G>A p.V41M | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.713); catalogued as COSV66796639; called by muse, mutect2, varscan2
- TMEM171 | c.740C>T p.P247L | Missense Mutation (SNP) | VAF 61/249 reads (24%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as rs755696036, COSV55131622; called by muse, mutect2, varscan2
- TMEM175 | c.1108C>T p.R370C | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as rs373083547; called by mutect2, varscan2
- TMEM33 | c.632T>C p.L211P | Missense Mutation (SNP) | VAF 34/174 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV100048951; called by muse, mutect2
- TMEM63C | c.2033G>A p.R678Q | Missense Mutation (SNP) | VAF 21/106 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs1399688353, COSV53607804; called by muse, mutect2, varscan2
- TMEM64 | c.889C>T p.R297W | Missense Mutation (SNP) | VAF 25/116 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs747707548, COSV69127804; called by muse, mutect2, varscan2
- TMIGD2 | c.244G>A p.G82R | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs761121311, COSV56668417; called by muse, mutect2, varscan2
- TMPO | c.295del p.T99Lfs*12 | Frame Shift Del (DEL) | VAF 48/162 reads (30%) | catalogued as rs770800449; called by mutect2, varscan2
- TMPRSS5 | c.128G>A p.R43H | Missense Mutation (SNP) | VAF 31/141 reads (22%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0.083); catalogued as rs745787689, COSV55424269; called by muse, mutect2, varscan2
- TNC | c.2916G>T p.K972N | Missense Mutation (SNP) | VAF 43/161 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.284); catalogued as COSV60789582; called by muse, mutect2, varscan2
- TNNT2 | c.284T>A p.V95E | Missense Mutation (SNP) | VAF 27/120 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV52665133; called by muse, mutect2, varscan2
- TNPO1 | c.2530del p.C844Vfs*45 | Frame Shift Del (DEL) | VAF 49/214 reads (23%) | catalogued as rs757314136; called by mutect2, pindel, varscan2
- TNPO3 | c.1198C>T p.R400C | Missense Mutation (SNP) | VAF 24/111 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1210989492, COSV55285990; called by muse, mutect2, varscan2
- TNRC6B | c.661G>A p.A221T | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.192); catalogued as COSV57306025; called by muse, mutect2, varscan2
- TP63 | c.521C>T p.P174L | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.858); catalogued as rs201188464, COSV53218669, COSV53223962; called by muse, mutect2, varscan2
- TPCN2 | c.554G>A p.R185Q | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs983333296, COSV53733225; called by muse, mutect2, varscan2
- TRIM35 | c.556C>T p.R186W | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs185776694, COSV59523915; called by muse, mutect2, varscan2
- TRIM59 | c.604del p.S202Vfs*3 | Frame Shift Del (DEL) | VAF 40/288 reads (14%) | catalogued as rs763112993; called by mutect2, varscan2
- TRPM2 | c.3989G>A p.R1330H | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs754137537, COSV55975575; called by muse, varscan2
- TRPM2 | c.4000C>T p.R1334C | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.506); catalogued as rs753208177, COSV55968301; called by muse, varscan2
- TRPS1 | c.1876G>A p.V626I (on ENST00000220888 / NM_001330599.2; = p.V639I on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 65/257 reads (25%) | SIFT tolerated, low confidence (0.85); PolyPhen benign (0.019); catalogued as rs181507248, COSV55258232; called by muse, mutect2, varscan2
- TRPV4 | c.2585G>A p.R862H | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); catalogued as rs371989034; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TSC1 | c.1976C>T p.A659V | Missense Mutation (SNP) | VAF 76/307 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.062); catalogued as rs118203609; ClinVar: not provided / benign / likely benign; called by muse, mutect2, varscan2
- TSEN2 | c.971C>T p.T324M | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs772061041, COSV53190669; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TSSK4 | c.737del p.K246Sfs*3 | Frame Shift Del (DEL) | VAF 12/67 reads (18%) | catalogued as rs1566657203; called by mutect2, pindel, varscan2
- TTC16 | c.2152C>T p.R718W | Missense Mutation (SNP) | VAF 45/193 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs751075295, COSV60162004; called by muse, mutect2, varscan2
- TTC21B | c.2941C>T p.R981C | Missense Mutation (SNP) | VAF 41/255 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as rs749278599, COSV54634400; called by muse, mutect2, varscan2
506 further variants in this file (167 protein-altering or splice-affecting, 323 silent, 16 other) are not listed here.
